Somatic mutation profile of tumor specimen SM-JU34T (aliquot 7316UP-1614) from CPTAC case C621273, project CPTAC-3 (Colon — Epithelial Neoplasms, NOS). Sex at birth: female; Vital status: Dead; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Colon, NOS.
Specimen SM-JU34T: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3963f241-1382-4657-bc0f-3f74ce7d97ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105218 (Blood Derived Normal), aliquot 7316UP-1614-1105218; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b8fdaaac-8cac-4aa3-b3df-cdd66647c3c4

The open-access MAF lists 2,149 somatic variants for this specimen: 1,403 protein-altering or splice-affecting, 445 silent, 301 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 957, Silent 445, Frame Shift Del 254, Intron 150, Frame Shift Ins 87, 3'UTR 46, Nonsense Mutation 46, RNA 38, 5'UTR 37, Splice Region 26, Splice Site 22, 5'Flank 19.

Variants (750 of 2,149; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPL | c.1171del p.R391Vfs*12 | Frame Shift Del (DEL) | VAF 88/277 reads (32%) | catalogued as rs751404811, CM045926, CM138787; ClinVar: likely pathogenic; called by mutect2, varscan2
- APC | c.4666dup p.T1556Nfs*3 | Frame Shift Ins (INS) | VAF 49/170 reads (29%) | catalogued as rs587783031, COSV57351096; ClinVar: uncertain significance / pathogenic; called by mutect2, pindel, varscan2
- ARG1 | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 74/272 reads (27%) | catalogued as rs104893944, CM993111; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 42/128 reads (33%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/286 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CCND3 | c.826C>T p.Q276* | Nonsense Mutation (SNP) | VAF 43/94 reads (46%) | hotspot (GDC flag); catalogued as COSV57828583; called by muse, mutect2, varscan2
- CFTR | c.2052del p.K684Nfs*38 | Frame Shift Del (DEL) | VAF 92/308 reads (30%) | catalogued as rs121908746; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL4A5 | c.973G>A p.G325R | Missense Mutation (SNP) | VAF 104/316 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs104886088, CM072961, CM920213, CM960349, COSV60370055; ClinVar: pathogenic; called by muse, mutect2, varscan2
- F8 | c.3637del p.I1213Ffs*5 | Frame Shift Del (DEL) | VAF 122/182 reads (67%) | catalogued as rs387906450, CD111376, CD930955, CX162002, COSV64271598; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- GRIN2B | c.99dup p.S34Qfs*25 | Frame Shift Ins (INS) | VAF 58/152 reads (38%) | catalogued as rs398122823; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- HUWE1 | c.9208C>T p.R3070C | Missense Mutation (SNP) | VAF 159/372 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs886041876, COSV53358976; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KDR | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 104/312 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1190050670, COSV55758808; called by muse, mutect2, varscan2
- KMT2D | c.10740G>A p.Q3580= | Splice Region (SNP) | VAF 52/120 reads (43%) | catalogued as rs398123700; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KMT2D | c.1940del p.P647Hfs*283 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | catalogued as rs770315135, CM119945, COSV56413885, COSV99040251; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- LRP2 | c.13139del p.P4380Hfs*46 | Frame Shift Del (DEL) | VAF 74/218 reads (34%) | catalogued as rs80338754; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- LTBP3 | c.132del p.P45Rfs*25 | Frame Shift Del (DEL) | VAF 36/121 reads (30%) | catalogued as rs1286042594; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- LZTR1 | c.27del p.Q10Rfs*15 | Frame Shift Del (DEL) | VAF 71/242 reads (29%) | catalogued as rs587777613; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 77/224 reads (34%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NEB | c.11601+6124C>T | Intron (SNP) | VAF 138/1136 reads (12%) | catalogued as rs1212374733; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PAK3 | c.343C>T p.R115* (on ENST00000262836 / NM_001324328.2; = p.R100* on NM_002578.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 77/254 reads (30%) | catalogued as rs780775497, COSV53279983; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 31/143 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PKHD1 | c.8162del p.P2721Qfs*14 | Frame Shift Del (DEL) | VAF 98/331 reads (30%) | catalogued as rs1057516775; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- SCN1A | c.4554dup p.P1519Tfs*18 (on ENST00000303395 / NM_001202435.3; = p.P1508Tfs*18 on NM_006920.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 97/394 reads (25%) | catalogued as rs794726825; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SLC18A2 | c.711dup p.F238Lfs*7 | Frame Shift Ins (INS) | VAF 64/190 reads (34%) | catalogued as rs762879329; ClinVar: likely pathogenic; called by mutect2, varscan2
- TP53 | c.455del p.P152Rfs*18 | Frame Shift Del (DEL) | VAF 72/229 reads (31%) | catalogued as rs730882019, CD147772, CM941327, COSV52666949, COSV52773466, COSV53038279; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ZNF469 | c.10248del p.R3417Gfs*56 (on ENST00000437464; = p.R3445Gfs*56 on NM_001367624.2) | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as rs764470052, COSV99081573; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABCA12 | c.6960C>T p.T2320= (on ENST00000272895 / NM_173076.3; = p.T2002= on NM_015657.3) | Splice Region (SNP) | VAF 102/288 reads (35%) | catalogued as rs1021345094, COSV55952672; called by muse, mutect2, varscan2
- ABCA13 | c.5198G>A p.R1733H | Missense Mutation (SNP) | VAF 98/298 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.187); catalogued as rs766374669, COSV70028369; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 20/74 reads (27%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCA9 | c.3338G>A p.G1113D | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376048173; called by muse, mutect2, varscan2
- ABCB11 | c.667C>T p.R223C | Missense Mutation (SNP) | VAF 107/345 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.961); catalogued as rs199841445, CM117170; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCB5 | c.3080G>A p.R1027H (on ENST00000404938 / NM_001163941.2; = p.R582H on NM_178559.6) | Missense Mutation (SNP) | VAF 98/290 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs745749100, COSV51703658, COSV51718688; called by muse, mutect2, varscan2
- ABCC5 | c.3269del p.L1090Cfs*26 | Frame Shift Del (DEL) | VAF 36/124 reads (29%) | catalogued as rs749943218; called by mutect2, varscan2
- ABCG1 | c.638G>A p.R213Q | Missense Mutation (SNP) | VAF 68/198 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.883); catalogued as rs772470306, COSV59202048; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 179/590 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs201696615; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC005324.2 | c.1349T>C p.L450P | Missense Mutation (SNP) | VAF 46/126 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.367); catalogued as rs1399711435; called by muse, mutect2, varscan2
- AC008397.2 | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs1354369697; called by muse, mutect2, varscan2
- AC231657.3 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.12); catalogued as COSV100540123; called by muse, mutect2, varscan2
- ACACB | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs754505331; called by muse, mutect2, varscan2
- ACO1 | c.2272C>T p.R758W | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs201421085; called by muse, mutect2, varscan2
- ACTL8 | c.290del p.P97Lfs*2 | Frame Shift Del (DEL) | VAF 56/177 reads (32%) | catalogued as rs1557449414; called by mutect2, pindel, varscan2
- ADAMTS20 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253174139, COSV67129756, COSV67135057; called by muse, mutect2, varscan2
- ADAMTS7 | c.3515C>T p.P1172L | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV66309397; called by muse, mutect2, varscan2
- ADAMTSL5 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as COSV100389280; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 27/59 reads (46%) | catalogued as rs760140619; called by mutect2, varscan2
- ADSS1 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 77/211 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200568797; called by muse, mutect2, varscan2
- AEBP1 | c.2841C>A p.N947K | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56261731, COSV99788811; called by muse, mutect2
- AEBP2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); catalogued as rs982709279; called by muse, mutect2, varscan2
- AFF3 | c.1255A>G p.S419G | Missense Mutation (SNP) | VAF 57/172 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs760333652, COSV57842263; called by mutect2, varscan2
- AGGF1 | c.1339C>T p.R447* | Nonsense Mutation (SNP) | VAF 69/232 reads (30%) | catalogued as rs376959475; called by muse, mutect2, varscan2
- AGRN | c.3589G>A p.G1197S | Missense Mutation (SNP) | VAF 155/452 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.083); catalogued as rs886460165; called by muse, mutect2, varscan2
- AHNAK | c.935C>T p.P312L | Missense Mutation (SNP) | VAF 72/169 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs540814813; called by muse, mutect2, varscan2
- AHNAK2 | c.13787C>T p.T4596M | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1407036271, COSV60921135; called by muse, mutect2
- AJAP1 | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 33/83 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.864); catalogued as COSV65450662, COSV65451766; called by muse, mutect2, varscan2
- AK5 | c.1549C>T p.R517C (on ENST00000354567 / NM_174858.3; = p.R491C on NM_012093.4) | Missense Mutation (SNP) | VAF 60/184 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs144951885; called by muse, varscan2
- AK9 | c.3625del p.R1209Gfs*39 | Frame Shift Del (DEL) | VAF 17/51 reads (33%) | catalogued as rs778351035; called by mutect2, pindel, varscan2
- AKAP11 | c.1316C>T p.A439V | Missense Mutation (SNP) | VAF 76/295 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.031); catalogued as rs949131444; called by muse, mutect2, varscan2
- AL133500.1 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.23); catalogued as rs368985442; called by muse, mutect2, varscan2
- ALAD | c.683del p.P228Lfs*24 | Frame Shift Del (DEL) | VAF 118/413 reads (29%) | catalogued as rs1564369378; called by mutect2, pindel, varscan2
- ALG12 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 99/333 reads (30%) | PolyPhen possibly damaging (0.882); catalogued as rs769555808; called by muse, mutect2, varscan2
- AMIGO2 | c.1271G>A p.C424Y | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56973924; called by muse, mutect2, varscan2
- AMPD2 | c.2381G>A p.C794Y | Missense Mutation (SNP) | VAF 131/416 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV56647784; called by muse, mutect2, varscan2
- ANGEL2 | c.437C>T p.T146M | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs190621865, COSV100853948; called by muse, mutect2, varscan2
- ANK1 | c.1717del p.L573Cfs*64 | Frame Shift Del (DEL) | VAF 7/39 reads (18%) | catalogued as CD014448; called by mutect2, pindel, varscan2
- ANKHD1-EIF4EBP3 | c.3400C>T p.R1134C | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1018081322; called by muse, mutect2
- ANKRD49 | c.208del p.M70Wfs*32 | Frame Shift Del (DEL) | VAF 56/141 reads (40%) | catalogued as rs753570186; called by mutect2, varscan2
- ANKS1A | c.2603G>T p.G868V | Missense Mutation (SNP) | VAF 49/172 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs764196187; called by muse, varscan2
- AP1M2 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs781427984, COSV51569707; called by muse, mutect2, varscan2
- AP2A1 | c.2551dup p.Q851Pfs*55 | Frame Shift Ins (INS) | VAF 30/91 reads (33%) | catalogued as rs1555794627; called by mutect2, varscan2
- APAF1 | c.698G>A p.R233H (on ENST00000551964 / NM_181861.2; = p.R222H on NM_001160.3) | Missense Mutation (SNP) | VAF 97/291 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs141157255; called by muse, mutect2, varscan2
- APBA2 | c.2096G>A p.R699H | Missense Mutation (SNP) | VAF 111/497 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV68788804; called by muse, mutect2, varscan2
- APBA3 | c.907G>A p.V303M | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.636); catalogued as rs746107677; called by muse, mutect2, varscan2
- APOBR | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.522); catalogued as rs1226606108; called by muse, mutect2, varscan2
- ARHGAP39 | c.1805C>T p.A602V | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as rs948752387; called by muse, mutect2, varscan2
- ARHGEF1 | c.1861C>T p.R621C | Missense Mutation (SNP) | VAF 81/234 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782497331, COSV61526594; called by muse, mutect2, varscan2
- ARHGEF12 | c.4229G>A p.R1410H | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs202128571; called by muse, mutect2, varscan2
- ARHGEF17 | c.6127G>A p.G2043S | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs368547430; called by muse, mutect2, varscan2
- ARID1A | c.5548del p.D1850Tfs*33 | Frame Shift Del (DEL) | VAF 54/172 reads (31%) | catalogued as COSV61389445; called by pindel, varscan2
- ARID1B | c.1243del p.A415Pfs*15 | Frame Shift Del (DEL) | VAF 5/26 reads (19%) | catalogued as rs1417035592; called by mutect2, pindel, varscan2
- ARID2 | c.2554C>T p.Q852* | Nonsense Mutation (SNP) | VAF 69/193 reads (36%) | catalogued as rs925229355; called by muse, mutect2, varscan2
- ARRB1 | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 40/177 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs776740350, COSV63576778; called by muse, mutect2, varscan2
- ARRB2 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 83/276 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.012); catalogued as rs1247288395, COSV52619383; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 53/167 reads (32%) | catalogued as rs753865255; called by mutect2, varscan2
- ARSK | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 82/232 reads (35%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.623); catalogued as rs374366998; called by muse, mutect2, varscan2
- ASB18 | c.1298G>A p.R433H | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749930126, COSV58236116; called by muse, mutect2
- ASXL1 | c.2462A>G p.D821G | Missense Mutation (SNP) | VAF 98/263 reads (37%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); catalogued as rs780896078; called by muse, mutect2, varscan2
- ATAD2 | c.354del p.E119Kfs*8 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | catalogued as rs746676748; called by mutect2, varscan2
- ATP11B | c.2650del p.Y884Ifs*30 | Frame Shift Del (DEL) | VAF 14/36 reads (39%) | catalogued as rs759638000; called by mutect2, varscan2
- ATP1A2 | c.2813G>A p.R938H | Missense Mutation (SNP) | VAF 165/453 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs759097524, COSV100767806, COSV100768062; called by muse, mutect2, varscan2
- B3GAT1 | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.502); catalogued as rs965181801; called by muse, mutect2, varscan2
- B3GNTL1 | c.574G>A p.V192M | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs762230226, COSV57946545; called by muse, mutect2
- BAG2 | c.222C>T p.D74= | Splice Region (SNP) | VAF 20/60 reads (33%) | catalogued as rs756825488, COSV65786799; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCKDK | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 96/254 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.409); catalogued as rs374568685; called by muse, mutect2, varscan2
- BCL7C | c.295C>A p.Q99K | Missense Mutation (SNP) | VAF 71/235 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as COSV53062710; called by muse, mutect2, varscan2
- BCL9L | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs149904706; called by muse, varscan2
- BCLAF1 | c.2122C>T p.R708W | Missense Mutation (SNP) | VAF 47/178 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.764); catalogued as rs749172270, COSV50357499, COSV99219398; called by muse, mutect2, varscan2
- BDNF | c.479C>T p.S160L | Missense Mutation (SNP) | VAF 138/414 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs750030464, COSV100151992, COSV59234276; called by muse, mutect2, varscan2
- BEND7 | c.869G>A p.R290Q | Missense Mutation (SNP) | VAF 72/179 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs767454294, COSV61987407; called by muse, mutect2, varscan2
- BICDL2 | c.919G>A p.D307N | Missense Mutation (SNP) | VAF 81/195 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as COSV54157477; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2042A>C p.D681A | Missense Mutation (SNP) | VAF 64/222 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV100863735; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2899G>A p.A967T | Missense Mutation (SNP) | VAF 109/451 reads (24%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.001); catalogued as rs775996769, COSV63245635; called by muse, mutect2, varscan2
- BLVRA | c.695A>G p.H232R | Missense Mutation (SNP) | VAF 117/325 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.062); catalogued as rs1315965538; called by muse, mutect2, varscan2
- BRAF | c.2405C>T p.A802V (on ENST00000288602 / NM_001374244.1; = p.A762V on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 78/254 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs775889922, COSV56115442, COSV56368837; called by muse, mutect2, varscan2
- BRD7 | c.287G>A p.R96Q | Missense Mutation (SNP) | VAF 91/274 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as rs150539401; called by muse, mutect2, varscan2
- BRWD3 | c.4573G>A p.G1525S | Missense Mutation (SNP) | VAF 72/186 reads (39%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0); catalogued as rs771173711, COSV64752792; called by muse, mutect2, varscan2
- BTBD11 | c.1682C>T p.A561V (on ENST00000280758 / NM_001018072.2; = p.A98V on NM_001017523.2) | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1368588123, COSV55016681; called by muse, mutect2, varscan2
- BTNL3 | c.1200del p.S401Afs*7 | Frame Shift Del (DEL) | VAF 57/174 reads (33%) | catalogued as rs757227190; called by mutect2, pindel, varscan2
- BUB3 | c.373C>T p.P125S | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.164); catalogued as rs1445770507; called by muse, mutect2, varscan2
- C3orf49 | c.620del p.K207Rfs*14 | Frame Shift Del (DEL) | VAF 32/139 reads (23%) | catalogued as rs1466063805; called by mutect2, varscan2
- C4orf54 | c.4640del p.P1547Qfs*70 | Frame Shift Del (DEL) | VAF 31/74 reads (42%) | catalogued as rs763082793; called by mutect2, pindel, varscan2
- C6orf163 | c.174dup p.E59Rfs*19 | Frame Shift Ins (INS) | VAF 18/65 reads (28%) | catalogued as rs1184371126; called by mutect2, pindel, varscan2
- C8A | c.1271G>A p.R424Q | Missense Mutation (SNP) | VAF 129/380 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.046); catalogued as rs149254627; called by muse, mutect2, varscan2
- CACNG3 | c.544G>A p.G182R | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50064973; called by muse, mutect2, varscan2
- CALHM2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 103/288 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1278152148; called by muse, mutect2, varscan2
- CATSPER1 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 67/210 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs137878849; called by muse, mutect2, varscan2
- CAVIN3 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 88/237 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.106); catalogued as rs1475063142; called by muse, mutect2, varscan2
- CCDC115 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 45/135 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs752919660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CCDC166 | c.19C>T p.R7C | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1262427244; called by muse, mutect2, varscan2
- CCDC181 | c.1265del p.K422Sfs*6 (on ENST00000367806 / NM_001300969.1; = p.K421Sfs*6 on NM_021179.2) | Frame Shift Del (DEL) | VAF 34/118 reads (29%) | catalogued as rs759258977; called by mutect2, varscan2
- CCDC184 | c.511dup p.D171Gfs*44 | Frame Shift Ins (INS) | VAF 28/68 reads (41%) | catalogued as rs755249564; called by mutect2, varscan2
- CCDC58 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 80/258 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as COSV52246521; called by muse, mutect2, varscan2
- CCDC85A | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (0.49); PolyPhen benign (0.352); catalogued as rs757348777; called by muse, mutect2, varscan2
- CCDC97 | c.547dup p.L183Pfs*4 | Frame Shift Ins (INS) | VAF 21/68 reads (31%) | catalogued as rs865828858; called by mutect2, pindel, varscan2
- CCNY | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1473002179; called by muse, mutect2, varscan2
- CCR5 | c.382C>A p.L128M | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs201179081; called by muse, mutect2, varscan2
- CCT8L2 | c.1654dup p.I552Nfs*6 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | catalogued as rs780034402; called by mutect2, varscan2
- CD248 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.615); catalogued as rs751114440, COSV60936700; called by muse, mutect2, varscan2
- CDC42BPA | c.415A>G p.T139A | Missense Mutation (SNP) | VAF 46/138 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as rs146827361; called by muse, mutect2, varscan2
- CDH13 | c.859C>T p.R287C | Missense Mutation (SNP) | VAF 38/101 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.569); catalogued as rs376202554; called by muse, mutect2, varscan2
- CDK8 | c.757G>A p.D253N | Missense Mutation (SNP) | VAF 93/388 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.236); catalogued as COSV67419126; called by muse, mutect2, varscan2
- CDNF | c.493dup p.T165Nfs*2 | Frame Shift Ins (INS) | VAF 59/219 reads (27%) | catalogued as rs1245164692; called by mutect2, pindel, varscan2
- CDRT15L2 | c.692T>C p.V231A | Missense Mutation (SNP) | VAF 53/175 reads (30%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.302); catalogued as rs1257262707; called by muse, mutect2, varscan2
- CELF2 | c.1477C>T p.R493C (on ENST00000416382 / NM_001025077.3; = p.R506C on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV59976730; called by muse, mutect2, varscan2
- CELSR1 | c.2099C>T p.A700V | Missense Mutation (SNP) | VAF 119/333 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs147651051; called by muse, mutect2, varscan2
- CELSR3 | c.1392dup p.N465Qfs*25 | Frame Shift Ins (INS) | VAF 24/94 reads (26%) | catalogued as rs753657474; called by mutect2, pindel, varscan2
- CEMIP | c.1086+2T>G p.X362_splice | Splice Site (SNP) | VAF 170/390 reads (44%) | catalogued as COSV99586769; called by muse, mutect2, varscan2
- CERT1 | c.766C>T p.R256C (on ENST00000405807 / NM_001130105.1; = p.R128C on NM_005713.3) | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1214748516, COSV54657657; called by muse, mutect2, varscan2
- CFAP46 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 82/250 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as rs536559191, COSV100886078; called by muse, mutect2, varscan2
- CFAP54 | c.4253del p.K1418Rfs*4 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs1274191949; called by mutect2, varscan2
- CHAF1A | c.1028G>A p.R343H | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as rs758651234; called by muse, mutect2, varscan2
- CHD5 | c.5444C>T p.T1815M | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as rs573215215, COSV52409305; called by muse, mutect2, varscan2
- CHD7 | c.6193C>T p.R2065C | Missense Mutation (SNP) | VAF 102/322 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as CM117687, CM133772, CM147861, COSV101418091; called by muse, mutect2, varscan2
- CHRNB4 | c.1489C>T p.R497C | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs760548392, COSV55717198; called by muse, mutect2, varscan2
- CHST5 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.027); catalogued as rs1410066549; called by muse, varscan2
- CKB | c.431dup p.H145Afs*77 | Frame Shift Ins (INS) | VAF 66/220 reads (30%) | catalogued as rs749928387; called by mutect2, pindel, varscan2
- CLASP2 | c.2896del p.M966Wfs*33 (on ENST00000359576; = p.M965Wfs*33 on NM_015097.3 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 44/143 reads (31%) | catalogued as rs761731080; called by mutect2, varscan2
- CLEC4A | c.236dup p.T80Dfs*35 | Frame Shift Ins (INS) | VAF 42/116 reads (36%) | catalogued as rs1182229842; called by mutect2, varscan2
- CLIC5 | c.122G>T p.R41M | Missense Mutation (SNP) | VAF 63/237 reads (27%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.338); catalogued as COSV51754904; called by muse, mutect2, varscan2
- CLPTM1 | c.611G>A p.R204Q | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as COSV61613318; called by muse, mutect2, varscan2
- CLRN2 | c.435C>T p.G145= | Splice Region (SNP) | VAF 25/85 reads (29%) | catalogued as rs994079252; called by muse, mutect2, varscan2
- CLSTN2 | c.2211C>T p.Y737= | Splice Region (SNP) | VAF 23/65 reads (35%) | catalogued as rs148317543; called by muse, mutect2, varscan2
- CMKLR1 | c.746G>A p.R249H (on ENST00000312143 / NM_001142344.2; = p.R247H on NM_004072.3) | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760204829, COSV100379365; called by muse, mutect2, varscan2
- CNNM1 | c.773G>A p.R258Q | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs1231680009; called by muse, mutect2, varscan2
- CNTN1 | c.1745C>T p.T582I | Missense Mutation (SNP) | VAF 107/347 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.733); catalogued as rs374471716; ClinVar: likely benign; called by muse, mutect2, varscan2
- CNTNAP4 | c.511C>T p.R171* | Nonsense Mutation (SNP) | VAF 54/132 reads (41%) | catalogued as rs1013311455, COSV56671148; called by muse, mutect2, varscan2
- COL12A1 | c.5303G>A p.S1768N | Missense Mutation (SNP) | VAF 81/271 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs371310137; called by muse, mutect2, varscan2
- COL4A5 | c.2855C>A p.P952H | Missense Mutation (SNP) | VAF 56/183 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60358956; called by muse, mutect2, varscan2
- COL5A1 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 54/176 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0.039); catalogued as rs530442560; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A5 | c.3016G>A p.V1006M | Missense Mutation (SNP) | VAF 113/343 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as rs751443853, COSV55195783; called by muse, mutect2, varscan2
- COL7A1 | c.8506G>A p.V2836I | Missense Mutation (SNP) | VAF 149/487 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.044); catalogued as rs1246764789; called by muse, mutect2, varscan2
- COL7A1 | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 123/346 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as rs757643340, COSV60395303; called by muse, mutect2, varscan2
- CORO2B | c.1331G>A p.R444Q | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.158); catalogued as rs748303629; called by mutect2, varscan2
- COX4I2 | c.1-2A>G p.X1_splice | Splice Site (SNP) | VAF 108/292 reads (37%) | catalogued as rs1192963566; called by muse, mutect2, varscan2
- CPLANE1 | c.17G>T p.G6V (on ENST00000425232; = p.G78V on NM_023073.3) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554117507; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPPED1 | c.543G>T p.Q181H | Missense Mutation (SNP) | VAF 99/268 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.35); catalogued as COSV55497505; called by muse, mutect2, varscan2
- CPZ | c.1104G>A p.M368I (on ENST00000360986 / NM_001014447.3; = p.M357I on NM_003652.3) | Missense Mutation (SNP) | VAF 79/174 reads (45%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs866318508; called by muse, mutect2, varscan2
- CR2 | c.624del p.T209Hfs*10 | Frame Shift Del (DEL) | VAF 151/478 reads (32%) | catalogued as rs747832403; called by mutect2, varscan2
- CRACR2A | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 74/256 reads (29%) | catalogued as COSV61543578; called by muse, mutect2, varscan2
- CRB1 | c.3106G>A p.E1036K | Missense Mutation (SNP) | VAF 90/317 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as rs563857130, COSV66328727, COSV66328731; called by muse, mutect2, varscan2
- CREB3L2 | c.851A>T p.K284I | Missense Mutation (SNP) | VAF 55/153 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1403332874; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 12/34 reads (35%) | catalogued as rs747248693; called by mutect2, varscan2
- CRYBG2 | c.500G>A p.R167Q | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.07); catalogued as rs369844437; called by muse, mutect2, varscan2
- CTU1 | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 140/394 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70292656; called by muse, mutect2, varscan2
- CWF19L2 | c.287del p.K96Rfs*41 | Frame Shift Del (DEL) | VAF 8/27 reads (30%) | catalogued as rs772257590; called by mutect2, varscan2
- CYB5R2 | c.200G>T p.R67M | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55085436; called by muse, mutect2, varscan2
- CYC1 | c.276del p.S93Afs*161 | Frame Shift Del (DEL) | VAF 41/118 reads (35%) | catalogued as rs756254049; called by mutect2, varscan2
- CYP39A1 | c.270dup p.V91Sfs*4 | Frame Shift Ins (INS) | VAF 32/114 reads (28%) | catalogued as rs1225765844; called by mutect2, pindel, varscan2
- DCAF8 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 94/238 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as rs752089736, COSV58783348; called by muse, mutect2, varscan2
- DCAF8L1 | c.1069C>T p.Q357* | Nonsense Mutation (SNP) | VAF 30/123 reads (24%) | catalogued as COSV71595330; called by muse, mutect2, varscan2
- DDX20 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 52/179 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); catalogued as COSV63831144; called by muse, mutect2, varscan2
- DDX4 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.483); catalogued as rs771635664, COSV100737632; called by muse, mutect2, varscan2
- DDX60 | c.4843G>T p.G1615C | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.211); catalogued as COSV101190231; called by muse, mutect2, varscan2
- DGKQ | c.1699C>T p.R567W | Missense Mutation (SNP) | VAF 89/265 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1180775609; called by muse, mutect2, varscan2
- DHX34 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 115/350 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs201148024, COSV60895322; called by muse, mutect2, varscan2
- DIP2A | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 59/128 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.069); catalogued as rs369917913; called by muse, mutect2, varscan2
- DLC1 | c.1820C>T p.A607V (on ENST00000276297 / NM_001348081.2; = p.A170V on NM_006094.5) | Missense Mutation (SNP) | VAF 45/119 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs929788084, COSV52326811; called by muse, mutect2, varscan2
- DLGAP1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs759947491; called by muse, mutect2, varscan2
- DLGAP4 | c.1490C>T p.T497M | Missense Mutation (SNP) | VAF 105/316 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs192489219; called by muse, mutect2, varscan2
- DMBX1 | c.740del p.G247Vfs*15 | Frame Shift Del (DEL) | VAF 29/99 reads (29%) | catalogued as COSV63601642, COSV63602450; called by mutect2, pindel, varscan2
- DMXL2 | c.326dup p.L109Ffs*15 | Frame Shift Ins (INS) | VAF 68/287 reads (24%) | catalogued as rs752363479; called by mutect2, varscan2
- DNAH10 | c.5963G>A p.R1988H (on ENST00000409039; = p.R1927H on NM_207437.3) | Missense Mutation (SNP) | VAF 45/100 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs370827875; called by muse, mutect2, varscan2
- DNAH10 | c.8210C>T p.T2737M (on ENST00000409039; = p.T2676M on NM_207437.3) | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs756405690, COSV68989039; called by muse, mutect2, varscan2
- DNAH11 | c.11678C>T p.T3893M | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.286); catalogued as rs763843747, COSV60974905; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNMT3A | c.176del p.P59Rfs*13 | Frame Shift Del (DEL) | VAF 34/94 reads (36%) | catalogued as COSV53040261; called by mutect2, varscan2
- DOCK11 | c.3290A>G p.Q1097R | Missense Mutation (SNP) | VAF 78/201 reads (39%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.933); catalogued as COSV52234969; called by muse, mutect2, varscan2
- DPP10 | c.1312dup p.I438Nfs*7 | Frame Shift Ins (INS) | VAF 22/73 reads (30%) | catalogued as rs752853990; called by mutect2, pindel, varscan2
- DRC7 | c.1732G>A p.A578T | Missense Mutation (SNP) | VAF 60/177 reads (34%) | SIFT tolerated (0.99); PolyPhen benign (0.003); catalogued as rs778999719; called by muse, mutect2, varscan2
- DSEL | c.628dup p.I210Nfs*6 | Frame Shift Ins (INS) | VAF 56/218 reads (26%) | catalogued as rs1215181888; called by mutect2, pindel, varscan2
- DSG3 | c.427C>A p.L143I | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933771; called by muse, mutect2, varscan2
- DUOX2 | c.2215C>T p.R739C | Missense Mutation (SNP) | VAF 141/266 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs750639157, COSV66535311; called by muse, mutect2, varscan2
- DUSP22 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 55/283 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as COSV60527529; called by muse, mutect2, varscan2
- DYRK3 | c.1700C>A p.A567D | Missense Mutation (SNP) | VAF 33/107 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.468); catalogued as COSV100895664; called by muse, mutect2, varscan2
- E2F7 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 66/193 reads (34%) | catalogued as rs780614837, COSV59739397; called by muse, mutect2, varscan2
- E4F1 | c.1334C>T p.P445L | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.124); catalogued as rs765015745, COSV57040679, COSV57041008; called by muse, mutect2, varscan2
- ECPAS | c.4681G>A p.G1561R | Missense Mutation (SNP) | VAF 71/216 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs1367783816; called by muse, mutect2, varscan2
- EIF2B2 | c.973A>G p.I325V | Missense Mutation (SNP) | VAF 154/382 reads (40%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.826); catalogued as rs765712931; called by muse, mutect2, varscan2
- EIF5B | c.608del p.N203Ifs*10 | Frame Shift Del (DEL) | VAF 46/148 reads (31%) | catalogued as rs1176235101, COSV56813285; called by mutect2, varscan2
- ELK3 | c.525dup p.V176Rfs*14 | Frame Shift Ins (INS) | VAF 128/402 reads (32%) | catalogued as rs769175197; called by mutect2, varscan2
- EMILIN2 | c.2305G>A p.V769I | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.115); catalogued as rs201283611; called by muse, mutect2
- EML4 | c.1775C>T p.T592I | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.887); catalogued as rs1188101154; called by muse, mutect2, varscan2
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | catalogued as rs761717176; called by mutect2, varscan2
- EPB42 | c.580C>T p.R194C (on ENST00000441366 / NM_001114134.2; = p.R224C on NM_000119.3) | Missense Mutation (SNP) | VAF 66/738 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs139182437; called by muse, mutect2
- EPHA6 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs780254423, COSV67598252; called by muse, mutect2, varscan2
- ETS1 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60096717; called by muse, mutect2, varscan2
- EVL | c.560del p.P187Hfs*41 (on ENST00000402714 / NM_001330221.2; = p.P189Hfs*41 on NM_016337.3) | Frame Shift Del (DEL) | VAF 27/102 reads (26%) | catalogued as rs746606863; called by mutect2, varscan2
- EXO1 | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 94/311 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as rs750940919, COSV62218506; called by muse, mutect2, varscan2
- F8 | c.1640G>A p.C547Y | Missense Mutation (SNP) | VAF 151/479 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM054679, CM1314155; called by muse, mutect2, varscan2
- FAM117B | c.1598G>A p.G533D | Missense Mutation (SNP) | VAF 163/461 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.079); catalogued as COSV57419272; called by muse, mutect2, varscan2
- FAM135B | c.2408G>A p.S803N | Missense Mutation (SNP) | VAF 47/161 reads (29%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV52716667, COSV52755853; called by muse, mutect2, varscan2
- FAM155A | c.793G>A p.V265I | Missense Mutation (SNP) | VAF 97/424 reads (23%) | SIFT tolerated (0.39); PolyPhen benign (0.011); catalogued as rs202062814, COSV65586584; called by muse, mutect2, varscan2
- FAM186A | c.2261dup p.V755Gfs*16 | Frame Shift Ins (INS) | VAF 44/130 reads (34%) | catalogued as rs1325556099; called by mutect2, varscan2
- FAM187A | c.1066C>T p.R356W | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs1453848416; called by muse, mutect2
- FAM189B | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 92/263 reads (35%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.905); catalogued as rs1240159655, COSV63219355; called by muse, mutect2, varscan2
- FAM193B | c.2089C>T p.R697W | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs373410343; called by muse, mutect2, varscan2
- FAM20A | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 108/330 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0); catalogued as rs1335379646; called by muse, mutect2, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 55/146 reads (38%) | catalogued as rs748967872; called by mutect2, varscan2
- FAT2 | c.10383dup p.Y3462Lfs*26 | Frame Shift Ins (INS) | VAF 112/368 reads (30%) | catalogued as rs747011618; called by mutect2, varscan2
- FAT3 | c.8239C>T p.R2747W | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as rs200763217; called by muse, mutect2, varscan2
- FAT4 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 52/134 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs759309740, COSV67885713; called by muse, mutect2, varscan2
- FBXL7 | c.472C>T p.R158C | Missense Mutation (SNP) | VAF 114/303 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as rs1401076306; called by muse, mutect2, varscan2
- FBXW12 | c.1363A>G p.S455G | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.746); catalogued as rs201317090; called by muse, mutect2, varscan2
- FCGBP | c.6049G>A p.E2017K | Missense Mutation (SNP) | VAF 117/963 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.397); catalogued as rs1337616242; called by muse, mutect2, varscan2
- FDFT1 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as rs559977336; called by muse, mutect2, varscan2
- FERD3L | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs866406481, COSV51762348; called by muse, mutect2, varscan2
- FGF2 | c.17del p.G6Vfs*4 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | catalogued as rs776164719; called by mutect2, pindel, varscan2
- FHDC1 | c.2505del p.V836Sfs*25 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | catalogued as COSV52600528; called by mutect2, varscan2
- FHOD3 | c.1005del p.S336Vfs*138 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs777980924; called by mutect2, pindel, varscan2
- FITM1 | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 85/252 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.048); catalogued as rs900868217; called by muse, mutect2, varscan2
- FKBP1C | c.91C>T p.L31F | Missense Mutation (SNP) | VAF 84/261 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.664); catalogued as rs1178283539; called by muse, mutect2, varscan2
- FLNA | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 108/365 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM162870; called by muse, mutect2, varscan2
- FLT4 | c.89dup p.T31Dfs*15 | Frame Shift Ins (INS) | VAF 48/162 reads (30%) | catalogued as rs755445139; called by mutect2, varscan2
- FN1 | c.419G>A p.R140H | Missense Mutation (SNP) | VAF 117/384 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777763524, COSV100115678; called by muse, mutect2, varscan2
- FOXF2 | c.96del p.A33Pfs*89 | Frame Shift Del (DEL) | VAF 21/61 reads (34%) | catalogued as COSV99453578; called by mutect2, pindel, varscan2
- FOXL1 | c.350C>T p.P117L | Missense Mutation (SNP) | VAF 155/403 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV57213590; called by muse, mutect2, varscan2
- FOXN3 | c.1162G>A p.E388K (on ENST00000261302; = p.E366K on NM_005197.4) | Missense Mutation (SNP) | VAF 40/123 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs772625675, COSV54305153; called by muse, mutect2, varscan2
- FRAS1 | c.5783A>G p.H1928R | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as rs1471365312, COSV99356005; called by muse, mutect2, varscan2
- FREM3 | c.6398G>T p.S2133I | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.071); catalogued as rs965688625; called by muse, mutect2, varscan2
- FRMPD1 | c.2170G>A p.E724K | Missense Mutation (SNP) | VAF 83/251 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.165); catalogued as rs749927300; called by muse, mutect2, varscan2
- FRYL | c.989del p.L330* | Frame Shift Del (DEL) | VAF 44/135 reads (33%) | catalogued as rs1348158626; called by mutect2, varscan2
- FSIP2 | c.8038del p.T2680Hfs*3 | Frame Shift Del (DEL) | VAF 57/147 reads (39%) | catalogued as rs755234663; called by mutect2, varscan2
- FSIP2 | c.20133A>T p.K6711N | Missense Mutation (SNP) | VAF 73/233 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.936); catalogued as rs754643795; called by muse, mutect2, varscan2
- FUT1 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 111/367 reads (30%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.891); catalogued as rs150995632; called by muse, mutect2, varscan2
- FZD2 | c.1264G>A p.V422M | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs1339183245, COSV59527929; called by muse, mutect2, varscan2
- FZD9 | c.58G>A p.G20S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0.005); catalogued as rs782003819; called by muse, mutect2, varscan2
- GAD1 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 87/244 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.009); catalogued as rs1238959934, COSV60151582; called by muse, mutect2, varscan2
- GAD1 | c.755del p.X252_splice | Splice Site (DEL) | VAF 178/554 reads (32%) | catalogued as COSV60152140; called by mutect2, pindel, varscan2
- GALNT14 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV100204024; called by muse, mutect2, varscan2
- GALNT5 | c.1970dup p.N657Kfs*4 | Frame Shift Ins (INS) | VAF 36/133 reads (27%) | catalogued as rs778901995; called by mutect2, pindel, varscan2
- GALNT8 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 100/316 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0.047); catalogued as rs769100382, COSV52897296, COSV52900639; called by muse, mutect2, varscan2
- GART | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 67/164 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs757263290; called by muse, mutect2, varscan2
- GAS6 | c.1912G>A p.A638T | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs750814570, COSV59853160; called by muse, mutect2, varscan2
- GASK1B | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV56709593; called by muse, mutect2
- GATA2 | c.43G>A p.A15T | Missense Mutation (SNP) | VAF 76/209 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.434); catalogued as rs1413920280; called by muse, mutect2, varscan2
- GATAD2A | c.1094del p.P365Hfs*9 | Frame Shift Del (DEL) | VAF 66/223 reads (30%) | catalogued as rs35804366; called by mutect2, pindel, varscan2
- GCC1 | c.1769A>G p.D590G | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs1335179556; called by muse, mutect2, varscan2
- GDF1 | c.742del p.L248Wfs*27 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs938987727; called by mutect2, pindel
- GFRA1 | c.553G>A p.D185N | Missense Mutation (SNP) | VAF 85/266 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as rs754335579; called by muse, mutect2, varscan2
- GLB1 | c.2006dup p.N669Kfs*53 | Frame Shift Ins (INS) | VAF 106/313 reads (34%) | catalogued as rs759633494; called by mutect2, varscan2
- GLI2 | c.4100G>A p.R1367H (on ENST00000361492 / NM_001374353.1; = p.R1384H on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.013); catalogued as rs763852684; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLI3 | c.2588G>A p.R863H | Missense Mutation (SNP) | VAF 105/387 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1270096533; called by muse, mutect2, varscan2
- GLIS1 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs369266481, COSV56550362; called by muse, mutect2, varscan2
- GMEB2 | c.1450G>T p.G484C | Missense Mutation (SNP) | VAF 54/132 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV56609013; called by muse, mutect2
- GMIP | c.1966G>T p.D656Y | Missense Mutation (SNP) | VAF 55/179 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.106); catalogued as rs200618177; called by muse, mutect2, varscan2
- GNAL | c.854C>T p.A285V (on ENST00000269162 / NM_001142339.3; = p.A362V on NM_182978.4) | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.14); catalogued as COSV52334956; called by muse, mutect2, varscan2
- GNAS | c.181G>A p.V61I | Missense Mutation (SNP) | VAF 130/375 reads (35%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs587778390, COSV58345123, COSV58347881; ClinVar: not provided; called by muse, mutect2, varscan2
- GNAZ | c.745C>T p.R249C | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs1365180134, COSV50739124; called by muse, mutect2, varscan2
- GOLGA6C | c.2036del p.P679Rfs*? | Frame Shift Del (DEL) | VAF 121/297 reads (41%) | catalogued as rs773221176, COSV100316303; called by mutect2, pindel, varscan2
- GPR18 | c.361A>G p.M121V | Missense Mutation (SNP) | VAF 95/375 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.063); catalogued as rs748648382; called by muse, mutect2, varscan2
- GRIN3B | c.1837G>A p.V613I | Missense Mutation (SNP) | VAF 103/229 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.292); catalogued as rs79866475; called by muse, mutect2, varscan2
- GRM5 | c.3320C>T p.T1107M (on ENST00000305447 / NM_001143831.2; = p.T1075M on NM_000842.4) | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT tolerated, low confidence (0.26); PolyPhen probably damaging (0.966); catalogued as rs546269389; called by muse, mutect2, varscan2
- GTF2IRD2B | c.391G>A p.V131I | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.074); catalogued as rs1243072857; called by muse, mutect2, varscan2
- GTPBP3 | c.931G>A p.V311M | Missense Mutation (SNP) | VAF 82/206 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.553); catalogued as rs140393384; called by muse, mutect2, varscan2
- H1-0 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 69/187 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs773049853, COSV50649873; called by muse, mutect2, varscan2
- HDAC6 | c.3532G>A p.D1178N | Missense Mutation (SNP) | VAF 27/114 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.666); catalogued as rs782174981, COSV100491256; called by muse, mutect2, varscan2
- HDHD3 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as rs747591014, COSV53056601; called by muse, mutect2, varscan2
- HEATR5B | c.6214dup p.*2072Lfs*18 | Frame Shift Ins (INS) | VAF 24/66 reads (36%) | catalogued as rs1315552549; called by mutect2, varscan2
- HELLS | c.2161C>T p.R721C | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371792267; called by muse, mutect2, varscan2
- HELZ2 | c.6727C>T p.R2243C (on ENST00000467148 / NM_001037335.2; = p.R1674C on NM_033405.3) | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756636547; called by muse, mutect2, varscan2
- HERC2 | c.9089G>A p.S3030N | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.929); catalogued as rs201973387; called by muse, mutect2, varscan2
- HHIPL1 | c.529G>A p.D177N | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.612); catalogued as rs375351857, COSV58089097; called by muse, mutect2, varscan2
- HIGD1A | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs565556493, COSV58414573, COSV58414971; called by muse, mutect2, varscan2
- HK3 | c.2189G>A p.R730H | Missense Mutation (SNP) | VAF 88/252 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs745623940; called by muse, mutect2, varscan2
- HK3 | c.1753G>A p.V585M | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs754406639; called by muse, mutect2, varscan2
- HLA-B | c.343+1G>A p.X115_splice | Splice Site (SNP) | VAF 20/144 reads (14%) | catalogued as rs1168937188, COSV69520345, COSV69521733; called by muse, varscan2
- HLA-DQB1 | c.535del p.I180Lfs*12 | Frame Shift Del (DEL) | VAF 27/92 reads (29%) | catalogued as rs751976368; called by mutect2, pindel, varscan2
- HLTF | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.06); catalogued as rs372129397; called by muse, mutect2, varscan2
- HMCN2 | c.5063A>G p.E1688G | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.166); catalogued as rs548738574; called by muse, mutect2, varscan2
- HMCN2 | c.5926C>T p.R1976W | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.535); catalogued as rs577965469; called by muse, mutect2, varscan2
- HMGN2 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.974); catalogued as COSV52577298, COSV52578084; called by muse, mutect2, varscan2
- HOXD13 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 112/375 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs763149315, COSV66832773; called by muse, mutect2, varscan2
- HRH2 | c.580C>T p.P194S | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99199533; called by muse, mutect2, varscan2
- HS3ST1 | c.667G>A p.D223N | Missense Mutation (SNP) | VAF 117/333 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.122); catalogued as COSV50024246; called by muse, mutect2, varscan2
- HS6ST2 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1428531182; called by muse, mutect2, varscan2
- HSPBP1 | c.490C>T p.R164W | Missense Mutation (SNP) | VAF 131/336 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1355096967; called by muse, mutect2, varscan2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 33/107 reads (31%) | catalogued as rs747841314; called by mutect2, varscan2
- ICE1 | c.6476C>T p.A2159V | Missense Mutation (SNP) | VAF 48/139 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs375797140; called by muse, mutect2, varscan2
- IFT140 | c.526G>T p.G176C | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68488099; called by muse, mutect2, varscan2
- IGSF10 | c.5642G>A p.G1881D | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1477022137; called by muse, mutect2, varscan2
- IL11 | c.540del p.L181Cfs*3 | Frame Shift Del (DEL) | VAF 89/287 reads (31%) | catalogued as COSV99214838; called by mutect2, pindel, varscan2
- IL18R1 | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 25/60 reads (42%) | catalogued as COSV52125413; called by muse, varscan2
- IL1B | c.436C>T p.H146Y | Missense Mutation (SNP) | VAF 123/417 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1312684514; called by muse, mutect2, varscan2
- ILVBL | c.1614G>T p.K538N | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as rs1263662509; called by muse, mutect2, varscan2
- INHBA | c.802del p.E268Kfs*91 | Frame Shift Del (DEL) | VAF 31/108 reads (29%) | catalogued as COSV54219689, COSV54219996; called by mutect2, pindel, varscan2
- INO80E | c.531del p.D178Tfs*8 | Frame Shift Del (DEL) | VAF 11/35 reads (31%) | catalogued as rs1339809802; called by mutect2, pindel, varscan2
- INPP4A | c.2653C>T p.R885C (on ENST00000074304 / NM_001134224.1; = p.R846C on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/117 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777173666, COSV50785099, COSV99302563; called by muse, mutect2, varscan2
- INTS5 | c.1532G>A p.R511Q | Missense Mutation (SNP) | VAF 55/144 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.55); catalogued as rs756443040; called by muse, mutect2, varscan2
- IPO9 | c.502C>T p.R168C | Missense Mutation (SNP) | VAF 98/235 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.082); catalogued as rs1157160147, COSV64234766; called by muse, mutect2, varscan2
- IQSEC3 | c.565del p.V189Cfs*109 | Frame Shift Del (DEL) | VAF 42/164 reads (26%) | catalogued as COSV58283925; called by mutect2, pindel, varscan2
- IRS4 | c.1952del p.G651Efs*23 | Frame Shift Del (DEL) | VAF 118/437 reads (27%) | catalogued as COSV64532818; called by mutect2, pindel, varscan2
- IRX1 | c.1291C>T p.R431C | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs976102129; called by muse, mutect2
- IRX2 | c.1117C>A p.P373T | Missense Mutation (SNP) | VAF 89/217 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as rs775015331; called by muse, mutect2, varscan2
- IRX5 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 17/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58060067; called by muse, mutect2
- IRX6 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 92/258 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV51860590; called by muse, mutect2, varscan2
- ITIH1 | c.1783C>T p.Q595* | Nonsense Mutation (SNP) | VAF 40/113 reads (35%) | catalogued as rs757375117, COSV56255433; called by muse, mutect2, varscan2
- ITK | c.823G>A p.V275M | Missense Mutation (SNP) | VAF 128/329 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs780522355, COSV68435348, COSV68435382; called by muse, mutect2, varscan2
- ITPKB | c.179dup p.A61Sfs*24 | Frame Shift Ins (INS) | VAF 36/122 reads (30%) | catalogued as rs1240487177; called by mutect2, pindel, varscan2
- JADE2 | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.073); catalogued as rs763968541, COSV50911820; called by muse, mutect2, varscan2
- JRK | c.1594C>T p.R532C | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs375362605, COSV101401029; called by muse, mutect2, varscan2
- JRK | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs1283928169, COSV70630291; called by muse, mutect2, varscan2
- KBTBD13 | c.121C>T p.R41W | Missense Mutation (SNP) | VAF 71/272 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs775442274; called by muse, mutect2, varscan2
- KCNC1 | c.1370del p.K457Rfs*20 | Frame Shift Del (DEL) | VAF 74/246 reads (30%) | catalogued as COSV99789491; called by mutect2, varscan2
- KCNH8 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.178); catalogued as rs747522897; called by muse, mutect2, varscan2
- KCNJ4 | c.1195G>A p.A399T | Missense Mutation (SNP) | VAF 84/276 reads (30%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs776902829; called by muse, mutect2, varscan2
- KIAA1109 | c.14227C>T p.R4743C | Missense Mutation (SNP) | VAF 72/255 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs767116983, COSV52662892; called by muse, varscan2
- KIF4B | c.2183G>A p.R728Q | Missense Mutation (SNP) | VAF 99/275 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs374852803; called by muse, mutect2, varscan2
- KLHDC3 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.943); catalogued as rs962420421; called by muse, mutect2, varscan2
- KLHDC7A | c.2074G>A p.V692M | Missense Mutation (SNP) | VAF 99/243 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs185356965; called by muse, mutect2, varscan2
- KLHDC9 | c.387dup p.A130Rfs*5 | Frame Shift Ins (INS) | VAF 20/50 reads (40%) | catalogued as rs761803466; called by mutect2, varscan2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 15/91 reads (16%) | catalogued as rs749011008; called by mutect2, pindel, varscan2
- KLHL10 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs782043692; called by muse, mutect2, varscan2
- KLHL42 | c.1321_1325del p.N441Dfs*6 | Frame Shift Del (DEL) | VAF 92/336 reads (27%) | catalogued as rs774224353; called by mutect2, pindel, varscan2
- KMT2D | c.16086G>T p.K5362N | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as CD159008, COSV99982182; called by muse, mutect2, varscan2
- KNL1 | c.5884C>T p.L1962F (on ENST00000346991 / NM_170589.5; = p.L1936F on NM_144508.5) | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs939715110, COSV61151691; called by muse, mutect2, varscan2
- KRT23 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 74/211 reads (35%) | catalogued as rs773310417; called by muse, mutect2, varscan2
- KRT75 | c.182G>A p.S61N | Missense Mutation (SNP) | VAF 62/182 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768683532; called by muse, mutect2, varscan2
- KRTAP10-11 | c.709G>A p.V237M | Missense Mutation (SNP) | VAF 119/345 reads (34%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.992); catalogued as rs1555940261; called by muse, mutect2, varscan2
- LAMC3 | c.2336dup p.Q781Pfs*7 | Frame Shift Ins (INS) | VAF 28/100 reads (28%) | catalogued as rs765163533; called by mutect2, pindel
- LAMC3 | c.3647C>T p.A1216V | Missense Mutation (SNP) | VAF 125/417 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as rs753468963, COSV100736085; called by muse, mutect2, varscan2
- LHB | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 136/434 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.209); catalogued as rs551522078; called by muse, mutect2
- LHX3 | c.178G>A p.D60N (on ENST00000371748 / NM_178138.6; = p.D65N on NM_014564.5) | Missense Mutation (SNP) | VAF 108/318 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs146027009, COSV65583087; called by muse, mutect2, varscan2
- LHX5 | c.1201G>A p.V401M | Missense Mutation (SNP) | VAF 73/167 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs748221055, COSV55663654; called by muse, mutect2, varscan2
- LMAN1 | c.823-2del p.X275_splice | Splice Site (DEL) | VAF 40/118 reads (34%) | catalogued as rs765287063; called by mutect2, varscan2
- LMTK3 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 70/201 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99540831; called by muse, mutect2, varscan2
- LMTK3 | c.363C>T p.D121= | Splice Region (SNP) | VAF 25/66 reads (38%) | catalogued as rs1366358917; called by muse, mutect2, varscan2
- LOXL4 | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs369940076; called by muse, mutect2
- LRFN3 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 102/295 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.891); catalogued as rs760004767, COSV55818396; called by muse, mutect2, varscan2
- LRIT2 | c.1532dup p.A512Cfs*11 | Frame Shift Ins (INS) | VAF 14/65 reads (22%) | catalogued as rs1307233234; called by mutect2, pindel, varscan2
- LRRC53 | c.1097T>C p.V366A | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as rs1348693368; called by muse, mutect2
- LRRIQ3 | c.414del p.G139Dfs*20 | Frame Shift Del (DEL) | VAF 68/190 reads (36%) | catalogued as rs749244073; called by mutect2, pindel, varscan2
- LRRK1 | c.4975C>T p.R1659W | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1015630432, COSV52608388; called by muse, mutect2
- LRRTM1 | c.536G>A p.R179H | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54443224; called by muse, mutect2, varscan2
- LTB4R2 | c.901C>T p.R301* (on ENST00000528054; = p.R270* on NM_019839.5) | Nonsense Mutation (SNP) | VAF 186/542 reads (34%) | catalogued as rs1338381164; called by muse, mutect2, varscan2
- LTN1 | c.2100del p.V701Sfs*5 | Frame Shift Del (DEL) | VAF 27/89 reads (30%) | catalogued as rs753955477; called by mutect2, pindel, varscan2
- LYAR | c.238-2A>G p.X80_splice | Splice Site (SNP) | VAF 37/100 reads (37%) | catalogued as rs752937370; called by muse, mutect2, varscan2
- LYZL6 | c.71G>A p.R24H | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs766673424; called by muse, mutect2, varscan2
- MAGEB6 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.007); catalogued as rs775192724, COSV66872018; called by muse, mutect2, varscan2
- MAN1B1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 159/430 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs561918454; called by muse, mutect2, varscan2
- MAN2A2 | c.847dup p.R283Pfs*73 | Frame Shift Ins (INS) | VAF 30/148 reads (20%) | catalogued as rs1343354383; called by mutect2, pindel
- MAN2B1 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 93/248 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.077); catalogued as rs1435717493; called by muse, mutect2, varscan2
- MAN2B2 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.131); catalogued as rs373139515; called by muse, mutect2, varscan2
- MANBA | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 82/294 reads (28%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs1467022491; called by muse, mutect2, varscan2
- MAP1B | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 55/183 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs780650498, COSV57103118; called by muse, mutect2, varscan2
- MAP1LC3C | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 62/167 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as rs982683803; called by muse, mutect2, varscan2
- MBD2 | c.471dup p.G158Rfs*28 | Frame Shift Ins (INS) | VAF 32/111 reads (29%) | catalogued as rs755716804; called by mutect2, varscan2
- MBD3 | c.92G>T p.R31M | Missense Mutation (SNP) | VAF 86/236 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as COSV50083256; called by muse, varscan2
- MCM5 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs200021712, COSV53346220, COSV99331765; called by muse, mutect2, varscan2
- MDGA1 | c.1748C>T p.P583L | Missense Mutation (SNP) | VAF 68/187 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1561843973; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs1180255648; called by mutect2, pindel, varscan2
- MDM1 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs1392139007; called by muse, mutect2, varscan2
- MECOM | c.1839del p.G614Efs*30 (on ENST00000468789 / NM_001105078.4; = p.G802Efs*30 on NM_004991.4) | Frame Shift Del (DEL) | VAF 66/208 reads (32%) | catalogued as rs773080349; called by mutect2, varscan2
- MEGF8 | c.5779C>T p.R1927C (on ENST00000251268 / NM_001271938.2; = p.R1860C on NM_001410.3) | Missense Mutation (SNP) | VAF 65/174 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs368438075; called by muse, mutect2, varscan2
- MEI1 | c.3458G>A p.R1153Q | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs774663994; called by muse, mutect2, varscan2
- MESD | c.632del p.K211Rfs*6 | Frame Shift Del (DEL) | VAF 140/268 reads (52%) | catalogued as rs745891632; called by mutect2, varscan2
- MEX3B | c.1172C>T p.P391L | Missense Mutation (SNP) | VAF 35/50 reads (70%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs752952352, COSV61663584; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 114/247 reads (46%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MMP28 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.427); catalogued as rs751685683; called by muse, mutect2, varscan2
- MOB3A | c.275C>T p.S92L | Missense Mutation (SNP) | VAF 92/242 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as rs199687461; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 67/173 reads (39%) | catalogued as rs755830405; called by mutect2, varscan2
- MPEG1 | c.698G>A p.R233H | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs200732824; called by muse, mutect2, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 70/239 reads (29%) | catalogued as rs757691558; called by mutect2, pindel, varscan2
- MRPS31 | c.739del p.R247Gfs*15 | Frame Shift Del (DEL) | VAF 85/387 reads (22%) | catalogued as COSV100062133; called by mutect2, pindel, varscan2
- MRTFA | c.1220del p.P407Qfs*30 | Frame Shift Del (DEL) | VAF 41/137 reads (30%) | catalogued as rs34028511; called by mutect2, pindel, varscan2
- MTF1 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 108/302 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs773997656; called by muse, mutect2, varscan2
- MTG2 | c.1105G>A p.V369M | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs1366793741; called by muse, mutect2, varscan2
- MTM1 | c.963A>T p.L321F | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs782645058; called by muse, mutect2, varscan2
- MTUS2 | c.2595C>A p.S865R | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs866505175; called by muse, mutect2, varscan2
- MUC16 | c.3397del p.M1133* | Frame Shift Del (DEL) | VAF 38/111 reads (34%) | catalogued as rs754876491; called by mutect2, pindel, varscan2
- MUC4 | c.3640G>A p.A1214T | Missense Mutation (SNP) | VAF 78/220 reads (35%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.003); catalogued as rs1363380008; called by muse, varscan2
- MUC5B | c.1982G>A p.C661Y | Missense Mutation (SNP) | VAF 47/172 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762864911; called by muse, mutect2, varscan2
- MUC6 | c.6938C>T p.S2313L | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs367913682, COSV59962762; called by muse, mutect2, varscan2
- MYB | c.1315C>A p.Q439K | Missense Mutation (SNP) | VAF 51/184 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1476805948; called by muse, mutect2, varscan2
- MYBPC2 | c.2802del p.I937* | Frame Shift Del (DEL) | VAF 79/288 reads (27%) | catalogued as rs1368598634; called by mutect2, pindel, varscan2
- MYH2 | c.4537+1G>A p.X1513_splice | Splice Site (SNP) | VAF 123/390 reads (32%) | catalogued as rs567336764, COSV55435374; called by muse, mutect2, varscan2
- MYO10 | c.3667G>A p.G1223R | Missense Mutation (SNP) | VAF 130/390 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434873123, COSV57016082, COSV57017061; called by muse, varscan2
- MYO1C | c.1252G>A p.G418R (on ENST00000648651 / NM_001080779.2; = p.G383R on NM_033375.5) | Missense Mutation (SNP) | VAF 147/423 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764101826; called by muse, mutect2, varscan2
- MYO1F | c.1930C>T p.R644W | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.579); catalogued as rs373423000; called by muse, varscan2
- MYO3A | c.1259C>T p.T420I | Missense Mutation (SNP) | VAF 65/225 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as rs1339616970; called by muse, mutect2, varscan2
- MYPOP | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs533099876; called by muse, mutect2, varscan2
- NBEA | c.7722G>T p.Q2574H | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.926); catalogued as COSV100081274; called by muse, varscan2
- NCAN | c.2621C>T p.T874M | Missense Mutation (SNP) | VAF 73/207 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs148196919; called by muse, mutect2, varscan2
- NCAPH2 | c.1252C>T p.R418W | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.724); catalogued as rs200790371; called by muse, mutect2, varscan2
- NCOA1 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 68/266 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.698); catalogued as rs749644300, COSV56042370; called by muse, mutect2, varscan2
- NCOR2 | c.6460G>A p.A2154T | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT tolerated (0.26); PolyPhen benign (0.019); catalogued as rs368425851; called by muse, mutect2, varscan2
- NFATC1 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0.006); catalogued as rs767841094, COSV53699581; called by muse, mutect2
- NFE2 | c.854A>C p.K285T | Missense Mutation (SNP) | VAF 109/362 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV56457431; called by muse, varscan2
- NFE2 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 34/113 reads (30%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.942); catalogued as rs772353922, COSV56456302, COSV56456725; called by muse, varscan2
- NFIB | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV66621440; called by muse, mutect2, varscan2
- NLGN2 | c.49G>A p.G17R | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as rs1183734429; called by muse, mutect2, varscan2
- NLGN3 | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 98/350 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.021); catalogued as rs779160000, COSV62445806; called by muse, mutect2, varscan2
- NOL4L | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.97); PolyPhen benign (0.003); catalogued as rs753607764, COSV62889711; called by muse, mutect2, varscan2
- NOTCH3 | c.6233G>A p.R2078Q | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.281); catalogued as rs765403158, COSV54628708, COSV54639957; called by muse, varscan2
- NOVA1 | c.1234G>T p.G412* | Nonsense Mutation (SNP) | VAF 78/206 reads (38%) | catalogued as COSV99948426; called by muse, mutect2, varscan2
- NPBWR2 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs751123142, COSV63900540; called by muse, mutect2, varscan2
- NPHP3 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 125/313 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.138); catalogued as rs781537576; called by muse, mutect2, varscan2
- NPPA | c.448C>T p.R150W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778138090, COSV56738679, COSV56742702; called by muse, mutect2, varscan2
- NR1D1 | c.1075C>T p.R359C | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs373443634, COSV52840970; called by muse, mutect2, varscan2
- NRDE2 | c.812C>A p.P271H | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1239535998; called by muse, mutect2, varscan2
- NRM | c.187del p.L63Wfs*23 | Frame Shift Del (DEL) | VAF 40/134 reads (30%) | catalogued as rs757081047; called by mutect2, pindel
- NT5C1B | c.664C>T p.R222W (on ENST00000359846 / NM_001199086.2; = p.R162W on NM_033253.4) | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV58394824; called by muse, mutect2, varscan2
- NTAN1 | c.890del p.N297Mfs*63 | Frame Shift Del (DEL) | VAF 74/194 reads (38%) | catalogued as rs753931847; called by mutect2, varscan2
- NTNG1 | c.1453C>T p.R485C (on ENST00000370068 / NM_001113226.3; = p.R384C on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV64273714; called by muse, mutect2
- NTRK3 | c.139C>T p.R47W | Missense Mutation (SNP) | VAF 100/418 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs771206956, COSV58107419; called by muse, mutect2, varscan2
- NUGGC | c.1924G>A p.G642R | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT tolerated (0.72); PolyPhen benign (0.123); catalogued as rs371363580, COSV58439272; called by muse, mutect2, varscan2
- NUP88 | c.932C>T p.A311V | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs563564141, COSV56702610, COSV56708095; called by muse, mutect2, varscan2
- OBSCN | c.917G>A p.R306H | Missense Mutation (SNP) | VAF 98/258 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as COSV52779154; called by muse, mutect2, varscan2
- ODF3L2 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 16/39 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); catalogued as rs1363921950; called by muse, mutect2
- ONECUT3 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1309505312; called by muse, mutect2, varscan2
- OPRD1 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs758135542; called by muse, mutect2, varscan2
- OR10A7 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 59/172 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as rs751420573, COSV58277829; called by muse, mutect2, varscan2
- OR2D2 | c.173C>A p.P58H | Missense Mutation (SNP) | VAF 46/125 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100203819; called by muse, mutect2, varscan2
- OR2M3 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 54/177 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as rs777056408; called by muse, mutect2, varscan2
- OR4C6 | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV58605127; called by muse, mutect2, varscan2
- OR4M1 | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 82/522 reads (16%) | catalogued as rs550760273, COSV60061725; called by muse, mutect2, varscan2
- OR51S1 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs560546339, COSV59057342; called by muse, mutect2, varscan2
- OR5A1 | c.680C>T p.A227V | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); catalogued as rs796662079, COSV57378244; called by muse, mutect2, varscan2
- OR5D18 | c.706C>T p.R236C | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs775742265, COSV61737083; called by muse, mutect2, varscan2
- OR6Q1 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 83/193 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56932474; called by muse, mutect2, varscan2
- OR8J3 | c.88G>A p.V30I | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.014); catalogued as rs1319314823; called by muse, mutect2
- OS9 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV57784830, COSV99232899; called by muse, mutect2, varscan2
- OSBP2 | c.1887dup p.S630Lfs*79 | Frame Shift Ins (INS) | VAF 40/132 reads (30%) | catalogued as rs772802379; called by mutect2, varscan2
- OSBPL8 | c.1533G>T p.Q511H | Missense Mutation (SNP) | VAF 47/171 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99675854; called by muse, mutect2, varscan2
- OSGEP | c.721C>G p.L241V | Missense Mutation (SNP) | VAF 51/179 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); catalogued as COSV99248005; called by muse, mutect2, varscan2
- OSM | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs752168515; called by muse, mutect2, varscan2
- OSR1 | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 105/250 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); catalogued as rs975152724, COSV99693546; called by muse, mutect2, varscan2
- P2RY6 | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs370867718; called by muse, mutect2, varscan2
- PAN2 | c.2681A>G p.N894S (on ENST00000425394 / NM_001127460.3; = p.N890S on NM_014871.5) | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1312591669; called by muse, mutect2, varscan2
- PANK2 | c.876G>A p.M292I (on ENST00000316562 / NM_153638.3; = p.M1? on NM_024960.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.205); catalogued as rs1320530723; called by muse, mutect2, varscan2
- PASD1 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1464860454, COSV64855304; called by muse, mutect2, varscan2
- PCDH17 | c.1675del p.A559Rfs*11 | Frame Shift Del (DEL) | VAF 93/428 reads (22%) | catalogued as COSV64977233; called by mutect2, pindel, varscan2
- PCDH8 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 65/238 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1393972914; called by muse, mutect2, varscan2
- PCDH8 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 54/251 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.85); catalogued as COSV58812644; called by muse, mutect2, varscan2
- PCDHB7 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.83); catalogued as rs200476708; called by muse, mutect2, varscan2
- PCDHGA10 | c.1511C>A p.P504H | Missense Mutation (SNP) | VAF 66/164 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs201724090; called by muse, mutect2, varscan2
- PCID2 | c.818del p.K273Sfs*4 | Frame Shift Del (DEL) | VAF 59/303 reads (19%) | catalogued as rs760522684; called by mutect2, pindel, varscan2
- PCNX1 | c.4223C>A p.P1408H | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV53101478; called by muse, mutect2, varscan2
- PCNX3 | c.3295C>T p.P1099S | Missense Mutation (SNP) | VAF 91/223 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1276445785, COSV63137088; called by muse, mutect2, varscan2
- PDE6G | c.44G>T p.R15M | Missense Mutation (SNP) | VAF 77/190 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.273); catalogued as COSV100148699; called by muse, mutect2, varscan2
- PDGFD | c.640del p.I214Lfs*68 | Frame Shift Del (DEL) | VAF 62/216 reads (29%) | catalogued as rs1333395128; called by mutect2, pindel, varscan2
- PDHA2 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54782458; called by muse, mutect2, varscan2
- PGK1 | c.552G>T p.K184N | Missense Mutation (SNP) | VAF 102/354 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.319); catalogued as rs782795716; called by muse, mutect2, varscan2
- PHIP | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99244978; called by muse, mutect2, varscan2
- PHLPP1 | c.4717C>T p.R1573W | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs915094142; called by muse, mutect2, varscan2
- PHLPP2 | c.1473G>A p.R491= | Splice Region (SNP) | VAF 71/189 reads (38%) | catalogued as rs764209734; called by muse, mutect2, varscan2
- PIAS1 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 85/276 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV51031504; called by muse, mutect2, varscan2
- PIGZ | c.1467dup p.T490Dfs*2 | Frame Shift Ins (INS) | VAF 47/136 reads (35%) | catalogued as rs759867499; called by mutect2, varscan2
- PIK3CD | c.1326G>A p.W442* | Nonsense Mutation (SNP) | VAF 103/304 reads (34%) | catalogued as COSV63131381; called by muse, mutect2, varscan2
- PIK3R5 | c.1424G>A p.R475H | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.949); catalogued as rs747280160, COSV99353171; called by muse, mutect2, varscan2
- PITPNM3 | c.2044C>T p.R682C | Missense Mutation (SNP) | VAF 154/478 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs752293643, COSV52595119; called by muse, mutect2, varscan2
- PIWIL1 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 68/232 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs538546986, COSV55350951, COSV99806980; called by muse, mutect2, varscan2
- PKD1 | c.11713-1G>T p.X3905_splice (on ENST00000262304 / NM_001009944.3; = p.X3904_splice on NM_000296.4) | Splice Site (SNP) | VAF 76/189 reads (40%) | catalogued as rs867092741, CS1313912; called by muse, mutect2, varscan2
- PKHD1L1 | c.7321G>A p.V2441I | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs533469873; called by muse, mutect2, varscan2
- PKN3 | c.2036_2038del p.K679del | In Frame Del (DEL) | VAF 24/86 reads (28%) | catalogued as rs747170999; called by pindel, varscan2
- PLEKHA7 | c.1603G>A p.G535S | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs753472835; called by muse, mutect2, varscan2
- PLEKHG5 | c.848C>T p.A283V (on ENST00000400915 / NM_001042663.3; = p.A246V on NM_020631.6) | Missense Mutation (SNP) | VAF 46/512 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1349934211; called by muse, mutect2
- PLXNA4 | c.2260C>T p.R754C | Missense Mutation (SNP) | VAF 79/193 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1284623467; called by muse, mutect2, varscan2
- PLXNB3 | c.4963del p.V1655Cfs*7 | Frame Shift Del (DEL) | VAF 27/66 reads (41%) | catalogued as rs782076287; called by mutect2, varscan2
- PMEPA1 | c.624del p.S209Afs*61 | Frame Shift Del (DEL) | VAF 31/97 reads (32%) | catalogued as rs751873496; called by mutect2, pindel, varscan2
- PML | c.908C>T p.A303V | Missense Mutation (SNP) | VAF 100/343 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.067); catalogued as rs754797325, COSV51450210; called by muse, mutect2, varscan2
- PNMA3 | c.261del p.W89Gfs*3 | Frame Shift Del (DEL) | VAF 40/104 reads (38%) | catalogued as COSV64722654; called by mutect2, varscan2
- PPARGC1A | c.1951C>T p.R651C | Missense Mutation (SNP) | VAF 71/226 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs143103266; called by muse, mutect2, varscan2
- PPFIA1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.212); catalogued as COSV54134324; called by muse, mutect2, varscan2
- PPL | c.626A>G p.Q209R | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1384372930; called by muse, mutect2, varscan2
- PPP1R8 | c.807del p.T270Hfs*34 (on ENST00000311772 / NM_014110.5; = p.T46Hfs*34 on NM_002713.4) | Frame Shift Del (DEL) | VAF 54/163 reads (33%) | catalogued as COSV52579842; called by mutect2, pindel, varscan2
- PPP4R3C | c.1556C>T p.T519I | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.234); catalogued as rs910971162; called by muse, mutect2, varscan2
- PPP6R1 | c.2515dup p.Q839Pfs*106 | Frame Shift Ins (INS) | VAF 38/126 reads (30%) | catalogued as rs550637760; called by mutect2, varscan2
- PPWD1 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs765426314; called by muse, mutect2
- PROM2 | c.532C>T p.R178C | Missense Mutation (SNP) | VAF 60/179 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as rs775648400, COSV58300905; called by muse, mutect2, varscan2
- PRPF38B | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as rs921122274; called by muse, mutect2, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 41/127 reads (32%) | catalogued as rs753236928; called by mutect2, varscan2
- PRRC2C | c.1399C>T p.R467W (on ENST00000367742; = p.R465W on NM_015172.4) | Missense Mutation (SNP) | VAF 79/269 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1281668603; called by muse, mutect2, varscan2
- PRSS55 | c.118C>T p.R40C | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs765848146; called by muse, mutect2, varscan2
- PTCH1 | c.3715C>T p.R1239W | Missense Mutation (SNP) | VAF 100/327 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.125); catalogued as rs758411912, COSV59499538; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PTCHD4 | c.2474G>A p.R825Q | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs746678221, COSV59780494; called by muse, mutect2, varscan2
- PTOV1 | c.1248dup p.*417Vfs*24 (on ENST00000391842; = p.*417Vfs*77 on NM_017432.5 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 24/72 reads (33%) | catalogued as rs750392317; called by mutect2, varscan2
- PTPRM | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 65/198 reads (33%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV59869807; called by muse, mutect2, varscan2
- PTPRS | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 125/408 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs200771602, COSV53637901; called by muse, mutect2, varscan2
- QRICH2 | c.4503G>T p.K1501N | Missense Mutation (SNP) | VAF 114/364 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53158610; called by muse, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 42/142 reads (30%) | catalogued as COSV100234622; called by mutect2, pindel, varscan2
- R3HDM4 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 45/118 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1246626354, COSV64293202; called by muse, mutect2, varscan2
- RAD54L | c.1099G>A p.A367T | Missense Mutation (SNP) | VAF 216/549 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as COSV100914848; called by muse, mutect2, varscan2
- RASAL2 | c.2684G>A p.R895H | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); catalogued as rs561944165; called by muse, mutect2, varscan2
- RASSF8 | c.797G>A p.R266Q | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140972036; called by muse, mutect2, varscan2
- RB1 | c.782C>T p.A261V | Missense Mutation (SNP) | VAF 92/395 reads (23%) | SIFT tolerated (0.49); PolyPhen benign (0.024); catalogued as rs776307088; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RBKS | c.922_923del p.Q308Vfs*38 | Frame Shift Del (DEL) | VAF 34/133 reads (26%) | catalogued as rs781204782; called by pindel, varscan2
- RBM20 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 76/287 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1362458012, COSV101051422; called by muse, mutect2, varscan2
- RBP3 | c.2884G>A p.A962T | Missense Mutation (SNP) | VAF 120/300 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as rs1426209551; called by muse, mutect2, varscan2
- RCSD1 | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63261369; called by muse, mutect2, varscan2
- RDX | c.1412del p.P471Lfs*35 | Frame Shift Del (DEL) | VAF 72/216 reads (33%) | catalogued as COSV100563010; called by mutect2, pindel, varscan2
- REEP5 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1415009098, COSV54842949; called by muse, mutect2, varscan2
- RFPL4B | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 55/154 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV101480729; called by muse, mutect2, varscan2
- RFX6 | c.1909G>T p.A637S | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs756030718, COSV60588807; called by muse, mutect2, varscan2
- RGS20 | c.319del p.L107Cfs*41 | Frame Shift Del (DEL) | VAF 42/130 reads (32%) | catalogued as rs747974681; called by mutect2, pindel, varscan2
- RHOBTB3 | c.1255C>T p.L419F | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.609); catalogued as rs1395541097; called by muse, mutect2, varscan2
- RING1 | c.517del p.E173Kfs*14 | Frame Shift Del (DEL) | VAF 27/91 reads (30%) | catalogued as rs761874510; called by mutect2, pindel, varscan2
- RLN2 | c.20del p.F7Sfs*4 | Frame Shift Del (DEL) | VAF 61/178 reads (34%) | catalogued as rs760343057; called by mutect2, varscan2
- RNF103 | c.525G>A p.M175I | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs966337273; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 125/212 reads (59%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- RNFT2 | c.407G>T p.G136V | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs775396476; called by muse, mutect2, varscan2
- ROBO1 | c.1781A>G p.Y594C | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1263628233; called by muse, mutect2, varscan2
- RP1L1 | c.1431G>T p.E477D | Missense Mutation (SNP) | VAF 53/142 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.159); catalogued as COSV66753808; called by muse, mutect2, varscan2
- RTKN | c.467G>T p.G156V (on ENST00000272430 / NM_001015055.2; = p.G143V on NM_033046.2) | Missense Mutation (SNP) | VAF 64/181 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV99269526; called by muse, mutect2, varscan2
- RUSF1 | c.541A>G p.M181V | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs1354161627; called by muse, mutect2, varscan2
- RYBP | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 72/249 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs1382885623, COSV72180845; called by muse, mutect2, varscan2
- RYR2 | c.13118G>A p.S4373N | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.239); catalogued as COSV63712535; called by muse, mutect2, varscan2
- SALL3 | c.2830G>A p.A944T | Missense Mutation (SNP) | VAF 54/125 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.005); catalogued as rs906293497, COSV73305790; called by muse, mutect2, varscan2
- SAMD11 | c.1352C>T p.T451M | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.68); catalogued as rs778084644; called by muse, mutect2, varscan2
- SARDH | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as rs766900566; called by muse, mutect2, varscan2
- SASH1 | c.3177del p.W1060Gfs*16 | Frame Shift Del (DEL) | VAF 125/181 reads (69%) | catalogued as rs761606832; called by mutect2, varscan2
- SBNO2 | c.812G>A p.R271H | Missense Mutation (SNP) | VAF 82/284 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62323536; called by muse, mutect2, varscan2
- SBSN | c.211G>A p.G71R | Missense Mutation (SNP) | VAF 58/148 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766134876; called by muse, mutect2, varscan2
- SCN11A | c.1472del p.K491Sfs*5 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as rs765136101; called by mutect2, varscan2
- SCNN1B | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs140945152; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- SCRN1 | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 37/121 reads (31%) | SIFT tolerated (0.74); PolyPhen benign (0.017); catalogued as rs775045104, COSV99620966; called by muse, mutect2, varscan2
- SDHB | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 115/358 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.939); catalogued as rs199948437, COSV64965419; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDK1 | c.6475A>G p.R2159G | Missense Mutation (SNP) | VAF 114/336 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.074); catalogued as rs1182892356; called by muse, mutect2, varscan2
- SDR9C7 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 45/138 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.19); catalogued as rs374434836; called by muse, mutect2, varscan2
- SEBOX | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs782660798; called by muse, mutect2, varscan2
- SELL | c.1119del p.G374Afs*8 (on ENST00000650983; = p.G361Afs*8 on NM_000655.5) | Frame Shift Del (DEL) | VAF 33/87 reads (38%) | catalogued as rs1421526852; called by mutect2, pindel, varscan2
- SEMA3F | c.425G>A p.C142Y | Missense Mutation (SNP) | VAF 73/213 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50037126; called by muse, mutect2, varscan2
- SEMA6C | c.1754C>T p.A585V | Missense Mutation (SNP) | VAF 60/218 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.061); catalogued as rs1266128628, COSV100501692; called by muse, mutect2, varscan2
- SEMG2 | c.493dup p.R165Kfs*9 | Frame Shift Ins (INS) | VAF 25/113 reads (22%) | catalogued as rs1281128483; called by mutect2, pindel, varscan2
- SERPINE1 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 113/340 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs867364951; called by muse, mutect2, varscan2
- SF3B2 | c.2625dup p.R876Tfs*16 | Frame Shift Ins (INS) | VAF 30/72 reads (42%) | catalogued as rs759211171; called by mutect2, varscan2
- SHANK2 | c.1237G>A p.A413T | Missense Mutation (SNP) | VAF 68/191 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.028); catalogued as rs782699631, COSV53589267, COSV99572189; called by muse, mutect2, varscan2
- SHROOM2 | c.4718C>T p.A1573V | Missense Mutation (SNP) | VAF 123/349 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs767591095; called by muse, mutect2, varscan2
- SI | c.887del p.L296* | Frame Shift Del (DEL) | VAF 41/139 reads (29%) | catalogued as rs769103567, COSV52291108; called by mutect2, pindel, varscan2
- SIGLEC11 | c.1193del p.P398Qfs*4 | Frame Shift Del (DEL) | VAF 28/86 reads (33%) | catalogued as rs774799128; called by mutect2, pindel, varscan2
- SLC16A8 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs770955283; called by muse, mutect2, varscan2
- SLC19A1 | c.67C>T p.R23W | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs772742675; called by muse, mutect2, varscan2
- SLC19A3 | c.259G>T p.G87C | Missense Mutation (SNP) | VAF 126/366 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.443); catalogued as rs200102807; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC30A3 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1162915438; called by muse, mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 115/178 reads (65%) | catalogued as rs750825208; called by mutect2, varscan2
- SLC45A1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 81/248 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775119911; called by muse, mutect2, varscan2
- SLC45A1 | c.2167T>C p.S723P | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs1247683382; called by muse, mutect2, varscan2
- SLC4A3 | c.470del p.H157Pfs*113 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs759883814, COSV56092392; called by mutect2, pindel, varscan2
- SLC4A3 | c.2102G>A p.R701Q | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.493); catalogued as rs1254650443; called by muse, mutect2, varscan2
- SLC4A7 | c.3355C>T p.R1119C | Missense Mutation (SNP) | VAF 61/211 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1161458423, COSV55394749; called by muse, mutect2, varscan2
- SLC4A9 | c.108C>A p.S36R | Missense Mutation (SNP) | VAF 146/409 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.05); catalogued as rs756572727; called by muse, mutect2, varscan2
- SLCO4C1 | c.1960G>A p.G654R | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs761404994; called by muse, mutect2, varscan2
- SLIT1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 109/303 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.077); catalogued as rs201085723; called by muse, mutect2, varscan2
- SLIT3 | c.1479C>A p.S493R | Missense Mutation (SNP) | VAF 74/187 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.014); catalogued as rs573099201; called by muse, mutect2, varscan2
- SLK | c.1105C>T p.R369C | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.17); catalogued as rs140715399; called by muse, mutect2, varscan2
- SMO | c.2186C>T p.A729V | Missense Mutation (SNP) | VAF 111/371 reads (30%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.01); catalogued as rs200751953, COSV50835094; called by muse, mutect2, varscan2
- SMPD3 | c.577G>A p.G193S | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200140589, COSV54711420; called by muse, mutect2, varscan2
- SNED1 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 145/324 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1045964670, COSV60028870; called by muse, mutect2, varscan2
- SNPH | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.988); catalogued as rs754975513; called by muse, mutect2, varscan2
- SOGA1 | c.1808G>A p.R603H | Missense Mutation (SNP) | VAF 96/275 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1435382042, COSV52914054; called by muse, mutect2, varscan2
- SORBS2 | c.3130dup p.E1044Gfs*8 (on ENST00000284776 / NM_021069.5; = p.E610Gfs*8 on NM_003603.6) | Frame Shift Ins (INS) | VAF 64/236 reads (27%) | catalogued as rs772549791, COSV52990153; called by mutect2, varscan2
- SOS1 | c.3883C>T p.R1295* | Nonsense Mutation (SNP) | VAF 150/452 reads (33%) | catalogued as COSV67674007; called by muse, mutect2, varscan2
- SOX9 | c.773_774dup p.L259Pfs*21 | Frame Shift Ins (INS) | VAF 92/289 reads (32%) | catalogued as CI098477, COSV55424224; called by mutect2, pindel, varscan2
- SPEG | c.3918del p.R1307Gfs*12 | Frame Shift Del (DEL) | VAF 47/144 reads (33%) | catalogued as rs771765677; called by mutect2, pindel, varscan2
- SPEN | c.10475C>T p.S3492F | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as COSV65270811, COSV65272110; called by muse, mutect2, varscan2
- SPINT2 | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 112/344 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.185); catalogued as rs1370702137; called by muse, mutect2, varscan2
- SPON2 | c.530G>A p.R177Q | Missense Mutation (SNP) | VAF 69/203 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as rs916082660; called by muse, mutect2, varscan2
- SPRING1 | c.22G>T p.V8L | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV54338575; called by muse, mutect2, varscan2
- SRCIN1 | c.3133C>T p.R1045W (on ENST00000621492; = p.R1011W on NM_025248.3) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1280191131; called by muse, mutect2, varscan2
- SRCIN1 | c.106G>A p.G36S | Missense Mutation (SNP) | VAF 67/171 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs552981903; called by muse, mutect2, varscan2
- SRP72 | c.25del p.V9Cfs*10 | Frame Shift Del (DEL) | VAF 14/44 reads (32%) | catalogued as rs763130641; called by mutect2, varscan2
- SRRM1 | c.983C>A p.P328Q | Missense Mutation (SNP) | VAF 71/237 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs570634850; called by muse, mutect2, varscan2
- SRRM5 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 112/309 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1318643822, COSV56194441; called by muse, mutect2, varscan2
- SRSF1 | c.405G>T p.Q135H | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99365351; called by muse, mutect2, varscan2
- SSR2 | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 92/279 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.594); catalogued as rs773535812, COSV99828631; called by muse, mutect2, varscan2
- STAG3 | c.173G>A p.R58H | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs775128180, COSV99444315; called by muse, mutect2, varscan2
- STAM | c.1484T>C p.V495A | Missense Mutation (SNP) | VAF 152/464 reads (33%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); catalogued as COSV66351441; called by muse, mutect2, varscan2
- STARD6 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57142002; called by muse, mutect2
- STK11IP | c.2956C>G p.P986A | Missense Mutation (SNP) | VAF 99/299 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as rs748673563; called by muse, mutect2, varscan2
- STON1 | c.793dup p.H265Pfs*20 | Frame Shift Ins (INS) | VAF 18/52 reads (35%) | catalogued as rs747498108; called by mutect2, pindel, varscan2
- STYX | c.290G>A p.R97H | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs554219196; called by muse, mutect2, varscan2
- SUN2 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs749230478, COSV53305031; called by muse, mutect2, varscan2
- SURF6 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs782465475; called by muse, mutect2, varscan2
- SVEP1 | c.9947C>T p.T3316M | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs201866666; called by muse, mutect2, varscan2
- SYCE1L | c.580G>A p.G194R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.019); catalogued as rs1266188546; called by muse, mutect2, varscan2
- SYNGAP1 | c.1066C>T p.R356C | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs144778033; ClinVar: likely benign; called by muse, mutect2, varscan2
- SYNM | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 284/544 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1472634299; called by muse, mutect2, varscan2
- SYVN1 | c.1603dup p.R535Pfs*10 (on ENST00000377190 / NM_172230.3; = p.R534Pfs*10 on NM_032431.3) | Frame Shift Ins (INS) | VAF 24/68 reads (35%) | catalogued as rs778345693; called by mutect2, varscan2
- TAB1 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 273/441 reads (62%) | SIFT tolerated (0.39); PolyPhen benign (0.03); catalogued as rs373883129; called by muse, mutect2, varscan2
- TACSTD2 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 132/341 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV64667085; called by muse, mutect2, varscan2
- TAF4 | c.2086G>A p.V696M | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs767742516, COSV53344057; called by muse, mutect2, varscan2
- TAF6 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV59842516; called by muse, mutect2, varscan2
- TANC1 | c.3011C>T p.A1004V | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); catalogued as rs759435249, COSV55084015, COSV55098286; called by muse, mutect2, varscan2
- TAOK3 | c.2477G>A p.R826H | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1019601490; called by muse, mutect2, varscan2
- TARS3 | c.1271dup p.L425Pfs*9 | Frame Shift Ins (INS) | VAF 50/130 reads (38%) | catalogued as rs1207173849; called by mutect2, pindel, varscan2
- TASP1 | c.1095A>C p.L365= | Splice Region (SNP) | VAF 30/86 reads (35%) | catalogued as rs747166003; called by muse, varscan2
- TBC1D23 | c.1947del p.K649Nfs*18 (on ENST00000394144 / NM_001199198.3; = p.K634Nfs*18 on NM_018309.5) | Frame Shift Del (DEL) | VAF 37/152 reads (24%) | catalogued as rs747637295, COSV61367528; called by mutect2, varscan2
- TBC1D32 | c.2435C>A p.P812H | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99251569; called by muse, mutect2, varscan2
- TBXT | c.256G>A p.A86T | Missense Mutation (SNP) | VAF 144/326 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51617239; called by muse, mutect2, varscan2
- TCF19 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs565850915; called by muse, mutect2, varscan2
- TCF25 | c.393del p.K131Nfs*17 | Frame Shift Del (DEL) | VAF 46/142 reads (32%) | catalogued as rs748021112; called by mutect2, varscan2
- TCTE1 | c.1003C>T p.R335C | Missense Mutation (SNP) | VAF 72/213 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs537656871, COSV104424281; called by muse, mutect2, varscan2
- TCTE1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 73/253 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs151164597, COSV65255558; called by muse, mutect2, varscan2
- TDP1 | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 112/289 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as rs113531329; called by muse, mutect2, varscan2
- TDRD6 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.868); catalogued as rs1351763540, COSV60177012; called by muse, mutect2, varscan2
- TECPR1 | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 81/233 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1457116947, COSV65784318; called by muse, mutect2, varscan2
- TENM1 | c.4600T>C p.Y1534H | Missense Mutation (SNP) | VAF 54/173 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV64431250; called by muse, mutect2, varscan2
- TENM3 | c.5548G>A p.V1850M | Missense Mutation (SNP) | VAF 47/144 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.703); catalogued as rs748357813; called by muse, mutect2, varscan2
- TENM4 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.04); catalogued as rs1481708121; called by muse, mutect2, varscan2
- TET2 | c.2735C>T p.A912V | Missense Mutation (SNP) | VAF 176/498 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs4145756, COSV54419646; called by muse, mutect2, varscan2
- TG | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated (0.88); PolyPhen benign (0.019); catalogued as rs759789389, COSV99600793; called by muse, mutect2, varscan2
- TGIF2LX | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 106/338 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as rs773693755, COSV99383199; called by muse, mutect2, varscan2
- THOC1 | c.144del p.K48Nfs*12 | Frame Shift Del (DEL) | VAF 34/93 reads (37%) | catalogued as rs746975641; called by mutect2, varscan2
- TIAM1 | c.3860del p.K1287Rfs*29 | Frame Shift Del (DEL) | VAF 66/210 reads (31%) | catalogued as COSV99734939; called by pindel, varscan2
- TIGD3 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 125/325 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); catalogued as COSV52887847; called by muse, mutect2, varscan2
- TKTL1 | c.1321A>G p.M441V | Missense Mutation (SNP) | VAF 68/184 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs936805186; called by muse, mutect2, varscan2
- TLCD3B | c.28dup p.V10Gfs*59 | Frame Shift Ins (INS) | VAF 14/43 reads (33%) | catalogued as rs780301705; called by mutect2, varscan2
- TLE3 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 48/82 reads (59%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as rs774554797, COSV58168716; called by muse, varscan2
- TMCC3 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); catalogued as rs1303417409; called by muse, mutect2, varscan2
- TMEM121B | c.1486C>A p.L496I | Missense Mutation (SNP) | VAF 142/418 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.066); catalogued as COSV58898378; called by muse, mutect2, varscan2
- TMEM132D | c.1567C>T p.R523W | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs144267550, COSV67160505, COSV67160591, COSV67162685; called by muse, mutect2, varscan2
- TMEM145 | c.1445G>A p.R482H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.034); catalogued as rs1467739554, COSV52090596, COSV52095927; called by muse, mutect2, varscan2
- TMEM260 | c.609G>A p.W203* | Nonsense Mutation (SNP) | VAF 39/134 reads (29%) | catalogued as rs955315296; called by muse, mutect2, varscan2
- TMEM267 | c.182G>A p.G61D | Missense Mutation (SNP) | VAF 81/295 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67992629; called by muse, mutect2, varscan2
- TMEM8B | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.113); catalogued as COSV65075677; called by muse, mutect2, varscan2
- TMPRSS7 | c.124C>T p.R42* | Nonsense Mutation (SNP) | VAF 101/332 reads (30%) | catalogued as rs753285417; called by muse, mutect2, varscan2
- TNFAIP1 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 149/474 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.608); catalogued as rs373733645; called by muse, mutect2, varscan2
- TNIP1 | c.563C>T p.A188V | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1340667932; called by muse, varscan2
- TNK2 | c.1482del p.D495Tfs*3 | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | catalogued as rs750898925, COSV100361004; called by mutect2, pindel, varscan2
- TOP2B | c.4321del p.S1441Vfs*41 (on ENST00000264331 / NM_001330700.2; = p.S1436Vfs*41 on NM_001068.3) | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | catalogued as rs1293862281; called by mutect2, pindel, varscan2
- TOX2 | c.730C>T p.P244S (on ENST00000358131 / NM_001098798.2; = p.P193S on NM_032883.3) | Missense Mutation (SNP) | VAF 36/138 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.339); catalogued as rs1186188793; called by muse, mutect2, varscan2
- TP73 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs770656238; called by muse, mutect2, varscan2
- TPP2 | c.3394G>A p.A1132T | Missense Mutation (SNP) | VAF 90/350 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); catalogued as rs1329723822; called by muse, mutect2, varscan2
- TPR | c.2959C>T p.R987C | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs556789304, COSV66599330; called by muse, mutect2, varscan2
- TRAF5 | c.1368del p.S457Hfs*26 | Frame Shift Del (DEL) | VAF 49/155 reads (32%) | catalogued as COSV99807703; called by mutect2, pindel, varscan2
- TRAF7 | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 108/313 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); catalogued as rs751318317, COSV58218349; called by muse, mutect2, varscan2
- TRAFD1 | c.1612G>A p.G538R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.866); catalogued as rs115008525; called by muse, mutect2
- TRAPPC11 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs577423330, COSV58216838; called by muse, mutect2, varscan2
- TRIM41 | c.944C>T p.S315L | Missense Mutation (SNP) | VAF 131/391 reads (34%) | SIFT tolerated (0.32); PolyPhen benign (0.139); catalogued as rs753810828; called by muse, mutect2, varscan2
- TRIM67 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 92/285 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100792225; called by muse, mutect2, varscan2
- TRIO | c.6092del p.L2031* | Frame Shift Del (DEL) | VAF 41/118 reads (35%) | catalogued as rs752676391; called by mutect2, varscan2
- TRIO | c.8228C>T p.T2743M | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as rs139314793; called by muse, mutect2, varscan2
- TRIP12 | c.4417C>A p.L1473I | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV52259212; called by muse, mutect2, varscan2
- TRMT12 | c.281C>A p.P94H | Missense Mutation (SNP) | VAF 92/267 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV60776624; called by muse, mutect2, varscan2
- TRPM2 | c.3820C>T p.P1274S | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.291); catalogued as COSV55976806; called by muse, mutect2, varscan2
- TRPM4 | c.3462G>A p.K1154= | Splice Region (SNP) | VAF 94/268 reads (35%) | catalogued as rs771732356; called by muse, mutect2, varscan2
- TRRAP | c.4802G>A p.R1601Q (on ENST00000359863 / NM_001244580.1; = p.R1583Q on NM_003496.3) | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.945); catalogued as rs782247298; called by muse, mutect2, varscan2
- TTBK2 | c.3310G>A p.D1104N | Missense Mutation (SNP) | VAF 155/279 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.918); catalogued as rs371341038, COSV99141078; called by muse, mutect2, varscan2
- TTC27 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 51/152 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200122950; called by muse, mutect2, varscan2
- TTN | c.61519G>A p.A20507T (on ENST00000591111; = p.A13083T on NM_003319.4) | Missense Mutation (SNP) | VAF 147/406 reads (36%) | PolyPhen benign (0.232); catalogued as rs794727433; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.2506G>A p.G836S (on ENST00000591111; = p.G790S on NM_003319.4) | Missense Mutation (SNP) | VAF 36/136 reads (26%) | PolyPhen probably damaging (0.962); catalogued as rs751157908, COSV59988553, COSV60007599; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TULP4 | c.2711G>A p.R904H | Missense Mutation (SNP) | VAF 57/161 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); catalogued as COSV65577457; called by muse, mutect2, varscan2
- TYR | c.1487T>C p.V496A | Missense Mutation (SNP) | VAF 113/352 reads (32%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1307528596; called by muse, mutect2, varscan2
- UBQLN3 | c.1777C>A p.P593T | Missense Mutation (SNP) | VAF 43/98 reads (44%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs756923573; called by muse, mutect2, varscan2
- UFL1 | c.1978del p.R660Gfs*17 | Frame Shift Del (DEL) | VAF 32/89 reads (36%) | catalogued as rs750472217; called by mutect2, varscan2
- UHRF1BP1 | c.3996del p.I1333Sfs*20 | Frame Shift Del (DEL) | VAF 68/152 reads (45%) | catalogued as COSV51954201; called by mutect2, pindel, varscan2
- UNC13D | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 112/307 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs776737156, CM112830, COSV52884054; called by muse, mutect2, varscan2
- UNC5B | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs753370821; called by muse, mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 28/138 reads (20%) | catalogued as rs767420916; called by mutect2, varscan2
- USH2A | c.15355C>T p.R5119W | Missense Mutation (SNP) | VAF 106/303 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as rs767137840, COSV56391560; called by muse, mutect2, varscan2
- USP13 | c.1896dup p.I633Hfs*5 | Frame Shift Ins (INS) | VAF 38/116 reads (33%) | catalogued as rs780272979; called by mutect2, varscan2
- USP35 | c.2290C>A p.L764M | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.871); catalogued as rs375971115; called by muse, mutect2, varscan2
- UTP14C | c.311dup p.Q105Afs*4 | Frame Shift Ins (INS) | VAF 200/890 reads (22%) | catalogued as rs1175995992; called by mutect2, varscan2
- VASP | c.551del p.P184Hfs*84 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | catalogued as rs762759767; called by mutect2, varscan2
- VLDLR | c.1666C>T p.R556* | Nonsense Mutation (SNP) | VAF 145/390 reads (37%) | catalogued as rs141396971; called by muse, mutect2, varscan2
- VPS13B | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 94/258 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as rs773472945, COSV62020498; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VPS13B | c.4384C>T p.R1462C | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs765547105, COSV62145591; called by muse, mutect2, varscan2
- VSTM2L | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 43/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1451937759; called by muse, mutect2, varscan2
- WDR27 | c.116G>A p.S39N | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs752929948; called by muse, mutect2, varscan2
- WDR70 | c.1822C>T p.R608C | Missense Mutation (SNP) | VAF 72/201 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs765801273, COSV54284222; called by muse, mutect2, varscan2
- WDR81 | c.1406C>T p.A469V | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.551); catalogued as rs1439677993, COSV58486177; called by muse, mutect2, varscan2
- WIPF2 | c.1288C>T p.R430C | Missense Mutation (SNP) | VAF 76/217 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765209297, COSV100063525, COSV100063743; called by muse, mutect2, varscan2
- WNK1 | c.2263G>A p.V755M (on ENST00000315939 / NM_018979.4; = p.V754M on NM_014823.3) | Missense Mutation (SNP) | VAF 129/353 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.156); catalogued as rs1444380006; called by muse, mutect2, varscan2
- WNT5A | c.619G>A p.A207T | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV99224822; called by muse, mutect2, varscan2
- WTIP | c.1226G>A p.R409H | Missense Mutation (SNP) | VAF 52/159 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.913); catalogued as COSV54328243; called by muse, mutect2, varscan2
- XIRP2 | c.5316del p.D1773Mfs*5 (on ENST00000628543; = p.D1948Mfs*5 on NM_152381.6) | Frame Shift Del (DEL) | VAF 47/149 reads (32%) | catalogued as rs760810271; called by mutect2, pindel, varscan2
- XPO4 | c.1444G>T p.G482* | Nonsense Mutation (SNP) | VAF 49/244 reads (20%) | catalogued as COSV99688362; called by muse, mutect2, varscan2
- XYLT2 | c.390G>T p.E130D | Missense Mutation (SNP) | VAF 71/182 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50017497; called by muse, mutect2, varscan2
- YY1AP1 | c.2279C>T p.P760L (on ENST00000295566 / NM_139118.2; = p.P703L on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 129/392 reads (33%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.969); catalogued as rs372287277; called by muse, mutect2, varscan2
- ZBTB3 | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 76/195 reads (39%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.735); catalogued as rs866849906; called by muse, mutect2, varscan2
- ZBTB34 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 29/255 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as rs561784372; called by muse, mutect2, varscan2
- ZFHX3 | c.658G>A p.A220T | Missense Mutation (SNP) | VAF 81/246 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs779915209; called by muse, mutect2, varscan2
- ZMIZ2 | c.1877C>T p.S626L | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1405506739, COSV54807197; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 78/180 reads (43%) | catalogued as rs753611080; called by mutect2, varscan2
- ZNF142 | c.2030G>A p.R677Q (on ENST00000411696 / NM_001379660.1; = p.R477Q on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as rs759292993, COSV101376949; called by muse, mutect2, varscan2
- ZNF16 | c.1540G>A p.D514N | Missense Mutation (SNP) | VAF 79/218 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs752265890, COSV52763616; called by muse, mutect2, varscan2
- ZNF174 | c.47C>A p.S16Y | Missense Mutation (SNP) | VAF 99/321 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.234); catalogued as COSV51902619; called by muse, mutect2, varscan2
- ZNF180 | c.1174C>T p.R392W | Missense Mutation (SNP) | VAF 79/176 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.159); catalogued as rs201078626; called by muse, mutect2, varscan2
- ZNF180 | c.208-3del | Splice Region (DEL) | VAF 77/257 reads (30%) | catalogued as rs1568425500; called by mutect2, pindel, varscan2
- ZNF217 | c.2546C>A p.P849H | Missense Mutation (SNP) | VAF 79/261 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.051); catalogued as COSV100184238, COSV56600266; called by muse, mutect2, varscan2
- ZNF292 | c.7032G>T p.K2344N | Missense Mutation (SNP) | VAF 46/95 reads (48%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.941); catalogued as COSV60536211; called by muse, mutect2, varscan2
- ZNF346 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 54/165 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99993213; called by muse, mutect2, varscan2
- ZNF439 | c.972dup p.L325Tfs*3 | Frame Shift Ins (INS) | VAF 62/178 reads (35%) | catalogued as rs1313557565; called by mutect2, pindel, varscan2
- ZNF45 | c.922G>T p.E308* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV54192846; called by mutect2, varscan2
- ZNF486 | c.607del p.I203Lfs*28 | Frame Shift Del (DEL) | VAF 44/118 reads (37%) | catalogued as rs1555718177; called by mutect2, pindel, varscan2
- ZNF518A | c.2785del p.T929Lfs*2 | Frame Shift Del (DEL) | VAF 38/128 reads (30%) | catalogued as rs781933025; called by mutect2, varscan2
- ZNF572 | c.18dup p.L7Tfs*7 | Frame Shift Ins (INS) | VAF 26/106 reads (25%) | catalogued as rs769734933; called by mutect2, varscan2
- ZNF592 | c.1879_1881del p.F627del | In Frame Del (DEL) | VAF 296/695 reads (43%) | catalogued as rs1250559095; called by pindel, varscan2
- ZNF609 | c.2201del p.K734Rfs*12 | Frame Shift Del (DEL) | VAF 132/238 reads (55%) | catalogued as rs760768847; called by mutect2, varscan2
- ZNF629 | c.377del p.P126Qfs*208 | Frame Shift Del (DEL) | VAF 23/71 reads (32%) | catalogued as COSV52698686; called by mutect2, pindel, varscan2
- ZNF672 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 47/138 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.074); catalogued as rs1365618651; called by muse, mutect2, varscan2
- ZNF684 | c.1027C>A p.L343I | Missense Mutation (SNP) | VAF 71/186 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.299); catalogued as COSV65519756; called by muse, mutect2, varscan2
- ZNF71 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 78/222 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.212); catalogued as rs562690323, COSV60150559; called by muse, mutect2, varscan2
- ZNF75D | c.901G>A p.E301K | Missense Mutation (SNP) | VAF 86/245 reads (35%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs139971483, COSV66133358; called by muse, mutect2, varscan2
- ZNRF4 | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); catalogued as rs201142539, COSV55773524; called by muse, mutect2, varscan2
- ZNRF4 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 100/298 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs370712403; called by muse, mutect2
- ZSCAN20 | c.2327G>A p.S776N | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.74); PolyPhen benign (0.014); catalogued as rs749010323; called by muse, mutect2, varscan2
- AADAT | c.395G>T p.G132V | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA10 | c.93del p.K31Nfs*18 | Frame Shift Del (DEL) | VAF 44/141 reads (31%) | called by mutect2, pindel, varscan2
- ABCA4 | c.1186G>A p.G396R | Missense Mutation (SNP) | VAF 161/440 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ABCD2 | c.1564A>G p.R522G | Missense Mutation (SNP) | VAF 61/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACACA | c.6899T>C p.V2300A | Missense Mutation (SNP) | VAF 167/487 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- ACOT6 | c.162G>T p.K54N | Missense Mutation (SNP) | VAF 66/158 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- ACSF2 | c.223G>A p.G75S | Missense Mutation (SNP) | VAF 62/205 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- ACVR2A | c.1156_1159del p.D386Cfs*6 | Frame Shift Del (DEL) | VAF 28/147 reads (19%) | called by pindel, varscan2
- ADAM10 | c.2212C>T p.R738* | Nonsense Mutation (SNP) | VAF 317/603 reads (53%) | called by muse, mutect2, varscan2
- ADAMTS3 | c.1922-1G>A p.X641_splice | Splice Site (SNP) | VAF 25/63 reads (40%) | called by muse, mutect2, varscan2
- ADAMTS9 | c.2661G>A p.W887* | Nonsense Mutation (SNP) | VAF 32/87 reads (37%) | called by muse, mutect2, varscan2
- ADAMTSL5 | c.263del p.P88Qfs*122 | Frame Shift Del (DEL) | VAF 41/131 reads (31%) | called by mutect2, pindel, varscan2
- ADCY1 | c.1492del p.R498Gfs*2 | Frame Shift Del (DEL) | VAF 39/119 reads (33%) | called by mutect2, pindel, varscan2
- ADCY4 | c.714_715del p.E238Dfs*21 | Frame Shift Del (DEL) | VAF 56/210 reads (27%) | called by pindel, varscan2
- ADCY7 | c.2020C>A p.L674M | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ADGRA1 | c.475G>A p.G159R | Missense Mutation (SNP) | VAF 37/77 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- ADGRB1 | c.1468C>T p.R490C | Missense Mutation (SNP) | VAF 12/282 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ADGRG4 | c.1027dup p.T343Nfs*16 | Frame Shift Ins (INS) | VAF 46/170 reads (27%) | called by mutect2, varscan2
- ADGRG6 | c.1836G>T p.Q612H | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- ADGRV1 | c.2447C>T p.P816L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADTRP | c.205del p.R69Efs*11 | Frame Shift Del (DEL) | VAF 35/157 reads (22%) | called by mutect2, pindel, varscan2
- AEN | c.838A>G p.S280G | Missense Mutation (SNP) | VAF 115/513 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- AGAP3 | c.1820G>A p.S607N (on ENST00000622464; = p.S643N on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AGBL5 | c.2086A>G p.R696G | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- AL662899.2 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ALLC | c.860C>A p.P287H | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
1,399 further variants in this file (655 protein-altering or splice-affecting, 445 silent, 299 other) are not listed here.
